Somatic mutation profile of tumor specimen TCGA-44-2656-01B (aliquot TCGA-44-2656-01B-06D-A271-08) from TCGA case TCGA-44-2656, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 59.6 years (21,766 days).
Specimen TCGA-44-2656-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1f57797f-0688-4767-8e44-3195c340f48c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-44-2656-10A (Blood Derived Normal), aliquot TCGA-44-2656-10A-01D-0969-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9b3d7404-46e3-4966-a5ce-7578ffbd6e22

The open-access MAF lists 774 somatic variants for this specimen: 600 protein-altering or splice-affecting, 159 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 499, Silent 159, Nonsense Mutation 58, Splice Site 19, Frame Shift Del 12, Splice Region 8, RNA 6, Intron 4, Frame Shift Ins 3, 5'UTR 2, 3'UTR 2, 5'Flank 1.

Variants (750 of 774; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 24/265 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519816, COSV54062198, COSV54062802; ClinVar: likely pathogenic; called by muse, mutect2
- AADACL2 | c.786G>A p.W262* | Nonsense Mutation (SNP) | VAF 34/145 reads (23%) | catalogued as COSV62929677; called by muse, mutect2, varscan2
- ABCA10 | c.3577G>T p.E1193* | Nonsense Mutation (SNP) | VAF 12/48 reads (25%) | catalogued as COSV52218722; called by muse, mutect2, varscan2
- ABCA13 | c.12366G>T p.K4122N | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV71284197; called by muse, mutect2, varscan2
- ABCA4 | c.426C>A p.H142Q | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.009); catalogued as COSV64671523; called by muse, mutect2, varscan2
- ABCA9 | c.661G>T p.V221F | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV60621424, COSV60627170; called by muse, mutect2
- ABCC9 | c.52G>C p.G18R | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); catalogued as COSV53964291; called by muse, mutect2, varscan2
- AC105001.2 | c.178G>T p.V60L | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.121); catalogued as COSV59108476; called by muse, mutect2
- ACSL1 | c.724G>T p.G242W | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55661049, COSV55666266; called by muse, mutect2, varscan2
- ACTG1 | c.136G>T p.G46C | Missense Mutation (SNP) | VAF 30/170 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.745); catalogued as COSV59509545, COSV59509810; called by muse, varscan2
- ADAM20 | c.285G>T p.Q95H | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); catalogued as COSV56454240; called by muse, mutect2
- ADAMTS16 | c.3591C>A p.C1197* | Nonsense Mutation (SNP) | VAF 4/42 reads (10%) | catalogued as COSV56980510; called by muse, mutect2, varscan2
- ADCY6 | c.1495G>T p.V499L | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57166513; called by muse, mutect2, varscan2
- ADGRG4 | c.3931C>T p.Q1311* | Nonsense Mutation (SNP) | VAF 21/68 reads (31%) | catalogued as rs1433246655, COSV54950883; called by muse, mutect2, varscan2
- ADGRL4 | c.844T>A p.F282I | Missense Mutation (SNP) | VAF 11/134 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV66059758; called by muse, mutect2
- AFF2 | c.631G>T p.E211* | Nonsense Mutation (SNP) | VAF 49/167 reads (29%) | catalogued as COSV60656743, COSV60659025; called by muse, mutect2, varscan2
- AFF4 | c.400C>T p.Q134* | Nonsense Mutation (SNP) | VAF 6/60 reads (10%) | catalogued as COSV54792178; called by muse, mutect2, varscan2
- AGL | c.790G>T p.G264W | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54048722, COSV54054032; called by muse, mutect2, varscan2
- AGO3 | c.399G>T p.W133C | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); catalogued as COSV55791675; called by muse, mutect2, varscan2
- AGXT2 | c.1483G>C p.D495H | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as COSV51484314; called by muse, mutect2
- AHNAK | c.8602G>T p.E2868* | Nonsense Mutation (SNP) | VAF 18/228 reads (8%) | catalogued as COSV57205592, COSV57221348; called by muse, mutect2
- AHNAK2 | c.2839G>T p.G947C | Missense Mutation (SNP) | VAF 34/352 reads (10%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as COSV60909246; called by muse, mutect2, varscan2
- ALDH1L1 | c.1480G>T p.D494Y | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56411309; called by muse, mutect2, varscan2
- ALK | c.1359G>T p.Q453H | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as COSV66559553; called by muse, mutect2, varscan2
- ALOX5 | c.437T>A p.M146K | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65551322; called by muse, mutect2
- ALPK2 | c.3485C>A p.A1162D | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.083); catalogued as COSV100864754, COSV64490735; called by muse, mutect2
- AMPD2 | c.442G>T p.E148* | Nonsense Mutation (SNP) | VAF 5/55 reads (9%) | catalogued as COSV56646529; called by muse, mutect2
- AP2A2 | c.2555A>T p.Q852L | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV59958409; called by muse, mutect2, varscan2
- APOB | c.2617C>A p.L873M | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV51925712; called by muse, mutect2, varscan2
- APOBEC4 | c.41C>T p.T14I | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58016983; called by muse, mutect2
- APOBR | c.2839G>T p.A947S (on ENST00000431282; = p.A956S on NM_018690.4) | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs1486024392, COSV60489064; called by muse, mutect2, varscan2
- ARFIP1 | c.567G>T p.M189I (on ENST00000353617 / NM_001287432.1; = p.M157I on NM_014447.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.017); catalogued as COSV61883385, COSV61886434; called by muse, mutect2, varscan2
- ARHGAP25 | c.1380C>A p.S460R (on ENST00000409202 / NM_001007231.3; = p.S452R on NM_014882.3) | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.348); catalogued as COSV54899273; called by muse, mutect2, varscan2
- ARHGAP33 | c.1814G>A p.R605Q | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.648); catalogued as rs139022184; called by muse, mutect2, varscan2
- ARID2 | c.1426C>T p.Q476* | Nonsense Mutation (SNP) | VAF 9/200 reads (5%) | catalogued as COSV57597421, COSV99044027; called by muse, mutect2
- ARMC5 | c.1085G>C p.R362P | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51655120, COSV51659726; called by muse, mutect2, varscan2
- ARSF | c.746G>C p.R249P | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63839074; called by muse, mutect2, varscan2
- ASB15 | c.323C>A p.T108N | Missense Mutation (SNP) | VAF 20/149 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV99306291; called by muse, mutect2, varscan2
- ASB2 | c.151A>G p.K51E | Missense Mutation (SNP) | VAF 6/105 reads (6%) | SIFT tolerated (0.75); PolyPhen benign (0.006); catalogued as COSV60110736; called by muse, mutect2
- ASPM | c.8315A>G p.Q2772R | Missense Mutation (SNP) | VAF 19/153 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV54125763; called by muse, mutect2, varscan2
- ASXL3 | c.3416C>A p.P1139H | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.007); catalogued as COSV99323798; called by mutect2, varscan2
- ATP13A2 | c.3034G>T p.V1012L | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.65); PolyPhen benign (0.046); catalogued as COSV58698526; called by muse, mutect2, varscan2
- ATP1A3 | c.2892G>T p.E964D (on ENST00000545399 / NM_001256214.2; = p.E951D on NM_152296.5) | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.191); catalogued as COSV57485662; called by muse, mutect2, varscan2
- ATP1B4 | c.844A>G p.I282V (on ENST00000218008 / NM_001142447.3; = p.I278V on NM_012069.5) | Missense Mutation (SNP) | VAF 68/204 reads (33%) | SIFT tolerated (0.72); PolyPhen benign (0.02); catalogued as COSV54311501; called by muse, mutect2, varscan2
- ATP4A | c.2542C>A p.R848S | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52866115; called by muse, mutect2
- ATXN1 | c.490G>T p.G164W | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.647); catalogued as COSV55207197, COSV55209691; called by muse, mutect2, varscan2
- BABAM2 | c.851+1G>T p.X284_splice | Splice Site (SNP) | VAF 10/54 reads (19%) | catalogued as COSV59617839, COSV59626067; called by muse, mutect2, varscan2
- BCAS1 | c.1153G>C p.D385H | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV65084225; called by muse, mutect2, varscan2
- BCAS1 | c.811G>T p.A271S | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.669); catalogued as COSV65084231; called by muse, mutect2, varscan2
- BDP1 | c.1961A>T p.H654L | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.013); catalogued as rs754948193, COSV62429287; called by muse, mutect2
- BIN2 | c.745G>C p.V249L | Missense Mutation (SNP) | VAF 45/200 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.213); catalogued as COSV57203914; called by muse, mutect2, varscan2
- BORA | c.853T>A p.S285T (on ENST00000613797; = p.S210T on NM_024808.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/176 reads (11%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.709); catalogued as COSV64694931; called by muse, mutect2, varscan2
- BRD8 | c.3488G>A p.R1163H | Missense Mutation (SNP) | VAF 24/347 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as rs757840348, COSV54522018; called by muse, mutect2
- BRINP3 | c.2026G>C p.D676H | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV66515010; called by muse, mutect2, varscan2
- BRIP1 | c.3601A>G p.I1201V | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); catalogued as rs1396175226, COSV51994991; called by muse, mutect2, varscan2
- BUB1B | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs587778144, COSV55010377; ClinVar: not provided; called by muse, mutect2, varscan2
- C1orf116 | c.1667C>A p.S556Y | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as COSV63943796; called by muse, mutect2
- C22orf42 | c.295C>A p.L99I | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT tolerated, low confidence (0.51); PolyPhen possibly damaging (0.567); catalogued as COSV66075359; called by muse, mutect2, varscan2
- C2orf78 | c.1831C>A p.Q611K | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.52); catalogued as COSV68516564; called by muse, mutect2, varscan2
- C3 | c.3382G>C p.E1128Q | Missense Mutation (SNP) | VAF 12/248 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.156); catalogued as COSV55569757, COSV55570157, COSV99837235; called by muse, mutect2
- C7 | c.1814T>A p.L605H | Missense Mutation (SNP) | VAF 10/169 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV57471632; called by muse, mutect2
- C8B | c.1119C>A p.N373K | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV64776652; called by muse, mutect2, varscan2
- C9orf64 | c.490G>T p.G164* | Nonsense Mutation (SNP) | VAF 22/115 reads (19%) | catalogued as COSV59032188; called by muse, mutect2, varscan2
- CACNA1E | c.5791G>T p.G1931C | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as COSV62383371, COSV62384187; called by muse, mutect2, varscan2
- CADPS | c.1137C>G p.I379M | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.011); catalogued as COSV51869717; called by muse, mutect2
- CALU | c.332G>T p.R111L | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as COSV50823286, COSV99975725; called by muse, mutect2, varscan2
- CAMK4 | c.452C>A p.A151E | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56663808; called by muse, mutect2, varscan2
- CAMTA1 | c.599A>G p.N200S | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.93); catalogued as rs1335374168, COSV57884758; called by muse, mutect2
- CARD11 | c.258G>T p.R86S | Missense Mutation (SNP) | VAF 68/326 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV62716163, COSV62716582; called by muse, varscan2
- CARMIL2 | c.544G>T p.D182Y | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100575991; called by muse, mutect2, varscan2
- CCDC171 | c.2564A>C p.K855T | Missense Mutation (SNP) | VAF 27/166 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV52634882; called by muse, mutect2, varscan2
- CCDC63 | c.1222G>T p.D408Y | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.748); catalogued as COSV57527263; called by muse, mutect2, varscan2
- CCNO | c.1027T>C p.C343R | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.526); catalogued as rs750464287, COSV57004411; called by muse, mutect2, varscan2
- CCT8L2 | c.1539G>C p.Q513H | Missense Mutation (SNP) | VAF 29/145 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.381); catalogued as COSV63461753, COSV63464025; called by muse, mutect2, varscan2
- CD163 | c.2960G>T p.G987V | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100775730, COSV63131323; called by muse, mutect2, varscan2
- CD163 | c.2959G>T p.G987W | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100775731; called by muse, mutect2, varscan2
- CD244 | c.785C>A p.T262N (on ENST00000368033 / NM_001166663.2; = p.T257N on NM_016382.4) | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.222); catalogued as rs1377239214, COSV59236441; called by muse, mutect2, varscan2
- CD244 | c.403G>T p.E135* (on ENST00000368033 / NM_001166663.2; = p.E130* on NM_016382.4) | Nonsense Mutation (SNP) | VAF 16/70 reads (23%) | catalogued as COSV59236463, COSV59237862; called by muse, mutect2, varscan2
- CD5L | c.895A>T p.K299* | Nonsense Mutation (SNP) | VAF 32/165 reads (19%) | catalogued as COSV63821247; called by muse, mutect2, varscan2
- CDH24 | c.2149C>T p.P717S | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.129); catalogued as rs1171193219, COSV57458935; called by muse, mutect2
- CEACAM18 | c.682G>C p.D228H | Missense Mutation (SNP) | VAF 38/181 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV67282317, COSV67283582; called by muse, mutect2, varscan2
- CEP126 | c.15G>T p.R5S | Missense Mutation (SNP) | VAF 51/159 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.668); catalogued as COSV54822265; called by muse, mutect2, varscan2
- CFAP299 | c.601C>A p.P201T | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63871884; called by mutect2, varscan2
- CFAP57 | c.133C>A p.Q45K | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.131); catalogued as COSV52539439; called by muse, mutect2, varscan2
- CFHR4 | c.249C>A p.C83* (on ENST00000367416 / NM_001201551.2; = p.C84* on NM_006684.5) | Nonsense Mutation (SNP) | VAF 21/124 reads (17%) | catalogued as COSV52225316; called by muse, mutect2, varscan2
- CFHR5 | c.1145C>A p.T382K | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.66); PolyPhen benign (0.007); catalogued as COSV56818614; called by muse, mutect2, varscan2
- CHD6 | c.3275A>T p.Y1092F | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.909); catalogued as COSV58554481; called by muse, mutect2
- CHST13 | c.137G>C p.G46A | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.473); catalogued as COSV60041502; called by muse, mutect2, varscan2
- CIC | c.1387A>G p.I463V | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.93); catalogued as COSV50549051; called by muse, mutect2, varscan2
- CIP2A | c.1924G>T p.D642Y | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55417434; called by muse, mutect2, varscan2
- CIT | c.841G>T p.G281C | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV55861941; called by muse, mutect2, varscan2
- CLASP1 | c.4265A>T p.Q1422L | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.034); catalogued as COSV55315566; called by muse, mutect2
- CLCN4 | c.1016G>C p.G339A | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66465375; called by muse, mutect2, varscan2
- CLDN14 | c.414G>T p.W138C | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59772018; called by muse, mutect2, varscan2
- CNGB3 | c.1179-1G>T p.X393_splice | Splice Site (SNP) | VAF 6/44 reads (14%) | catalogued as COSV60685706; called by muse, mutect2
- CNOT1 | c.1041A>T p.E347D | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as COSV57765739; called by muse, mutect2, varscan2
- CNTN2 | c.2914C>A p.P972T | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.03); catalogued as COSV59348479; called by muse, mutect2, varscan2
- CNTN4 | c.631C>A p.P211T | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.726); catalogued as COSV61868879; called by muse, mutect2, varscan2
- CNTNAP2 | c.1870C>A p.P624T | Missense Mutation (SNP) | VAF 29/128 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV62150646; called by muse, mutect2, varscan2
- CNTNAP5 | c.3214G>A p.G1072R | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs772641478, COSV70475477; called by mutect2, varscan2
- COBL | c.2142G>T p.K714N | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV54339812; called by muse, mutect2, varscan2
- COL27A1 | c.3338C>T p.P1113L | Missense Mutation (SNP) | VAF 33/162 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV61922285; called by muse, mutect2, varscan2
- COL3A1 | c.282+1G>T p.X94_splice | Splice Site (SNP) | VAF 7/32 reads (22%) | catalogued as COSV58582976; called by muse, mutect2, varscan2
- COL4A2 | c.2704G>T p.G902* | Nonsense Mutation (SNP) | VAF 8/69 reads (12%) | catalogued as COSV64625481; called by muse, mutect2, varscan2
- COL5A1 | c.1774G>T p.G592C | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65665879; called by muse, mutect2, varscan2
- COL5A2 | c.3797C>T p.P1266L | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.781); catalogued as COSV100880708, COSV66407652; called by muse, mutect2, varscan2
- CPEB1 | c.1621C>T p.Q541* (on ENST00000617958; = p.Q476* on NM_030594.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 22/85 reads (26%) | catalogued as COSV55617442; called by muse, mutect2, varscan2
- CPED1 | c.2839C>A p.Q947K | Missense Mutation (SNP) | VAF 34/171 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as COSV100120269; called by muse, mutect2, varscan2
- CRACD | c.2737G>T p.A913S | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.033); catalogued as COSV51716175; called by muse, mutect2, varscan2
- CRISPLD2 | c.998G>C p.R333P | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52277138; called by muse, mutect2, varscan2
- CRMP1 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 8/109 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV61478505; called by muse, mutect2
- CROT | c.1064G>T p.G355V | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58973012; called by muse, mutect2, varscan2
- CSMD2 | c.9173G>T p.W3058L | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53885674; called by muse, mutect2
- CSMD2 | c.1918G>T p.A640S | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT tolerated (0.8); PolyPhen benign (0.074); catalogued as COSV53885699, COSV53897184; called by muse, mutect2, varscan2
- CSMD3 | c.4107A>T p.Q1369H (on ENST00000297405 / NM_001363185.1; = p.Q1265H on NM_052900.3) | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.981); catalogued as COSV52116030; called by muse, mutect2, varscan2
- CSMD3 | c.1116C>A p.S372R | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV52116072; called by muse, mutect2, varscan2
- CSN3 | c.100G>C p.D34H | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.613); catalogued as COSV59243600; called by muse, mutect2, varscan2
- CT83 | c.137C>A p.S46Y | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.089); catalogued as COSV64140819; called by muse, mutect2, varscan2
- CTNNA2 | c.2154G>T p.M718I | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV100559222, COSV58138215; called by muse, mutect2, varscan2
- CTNND2 | c.1418G>T p.G473V | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.051); catalogued as COSV58869546; called by muse, mutect2, varscan2
- CUBN | c.10429C>A p.P3477T | Missense Mutation (SNP) | VAF 31/144 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1468596216, COSV64709163; called by muse, mutect2, varscan2
- CYP4F3 | c.552G>T p.E184D | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as COSV55407556; called by muse, mutect2, varscan2
- DCAF8L1 | c.101C>A p.A34E | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as COSV71595155; called by muse, mutect2, varscan2
- DCTN5 | c.136T>G p.C46G | Missense Mutation (SNP) | VAF 13/129 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.114); catalogued as COSV55614912; called by muse, mutect2
- DDC | c.570G>T p.Q190H | Missense Mutation (SNP) | VAF 31/242 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as COSV63564084; called by muse, mutect2, varscan2
- DEPDC7 | c.1263G>A p.K421= (on ENST00000241051 / NM_001077242.2; = p.K412= on NM_139160.2) | Splice Region (SNP) | VAF 27/141 reads (19%) | catalogued as COSV53806054; called by muse, mutect2, varscan2
- DGKB | c.2281G>T p.E761* | Nonsense Mutation (SNP) | VAF 53/307 reads (17%) | catalogued as COSV51765416; called by muse, mutect2, varscan2
- DIAPH3 | c.1699G>T p.E567* (on ENST00000400324 / NM_001042517.2; = p.E304* on NM_030932.3) | Nonsense Mutation (SNP) | VAF 3/15 reads (20%) | catalogued as COSV99932962; called by muse, mutect2
- DIO2 | c.512C>A p.A171E | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.048); catalogued as rs766090858, COSV70444863, COSV70445145; called by muse, mutect2, varscan2
- DIP2C | c.2554G>A p.E852K | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV55148506; called by muse, mutect2, varscan2
- DISP3 | c.3376-1G>T p.X1126_splice | Splice Site (SNP) | VAF 14/90 reads (16%) | catalogued as COSV53821800; called by muse, mutect2, varscan2
- DLL3 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 22/125 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.38); catalogued as COSV52693610; called by muse, mutect2, varscan2
- DNAH9 | c.9245A>T p.Q3082L | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52337591; called by mutect2, varscan2
- DSCAM | c.770G>A p.R257H | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.434); catalogued as rs373921750; called by muse, mutect2, varscan2
- DSCAML1 | c.1894G>T p.E632* (on ENST00000321322; = p.E572* on NM_020693.4) | Nonsense Mutation (SNP) | VAF 23/63 reads (37%) | catalogued as COSV58383444; called by muse, mutect2, varscan2
- DUOX1 | c.3085C>A p.Q1029K | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.14); catalogued as COSV58477926; called by muse, mutect2, varscan2
- DUSP22 | c.271G>T p.G91W | Missense Mutation (SNP) | VAF 23/222 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60524272; called by muse, mutect2
- DYNC1H1 | c.6397G>T p.E2133* | Nonsense Mutation (SNP) | VAF 5/43 reads (12%) | catalogued as COSV64134814; called by muse, mutect2, varscan2
- DYRK4 | c.1337A>G p.K446R | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV50537998; called by muse, mutect2, varscan2
- EBF2 | c.996G>C p.R332S | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); catalogued as COSV68776392, COSV68779949; called by muse, mutect2, varscan2
- EDIL3 | c.1398G>C p.R466S | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.918); catalogued as COSV56882919; called by muse, mutect2, varscan2
- EIF4A2 | c.976G>T p.V326F | Missense Mutation (SNP) | VAF 34/165 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as COSV56215789; called by muse, mutect2, varscan2
- ELF1 | c.1537C>G p.Q513E | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.137); catalogued as COSV53497380; called by muse, mutect2, varscan2
- ELF2 | c.1292C>G p.P431R (on ENST00000379550 / NM_001331036.2; = p.P371R on NM_006874.4) | Missense Mutation (SNP) | VAF 6/128 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as COSV55491892; called by muse, mutect2
- EMILIN2 | c.1090G>T p.G364* | Nonsense Mutation (SNP) | VAF 16/88 reads (18%) | catalogued as COSV54421597; called by muse, mutect2, varscan2
- ENAH | c.1432G>T p.E478* | Nonsense Mutation (SNP) | VAF 7/30 reads (23%) | catalogued as COSV52865586, COSV52868416; called by muse, mutect2, varscan2
- EPHA5 | c.2188C>A p.Q730K | Missense Mutation (SNP) | VAF 26/182 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56633773; called by muse, mutect2, varscan2
- EPHA6 | c.711C>A p.N237K | Missense Mutation (SNP) | VAF 40/283 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.068); catalogued as COSV67561544; called by muse, mutect2, varscan2
- EPHA7 | c.2500G>A p.E834K | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65178175; called by muse, mutect2, varscan2
- EPX | c.171-2A>T p.X57_splice | Splice Site (SNP) | VAF 15/237 reads (6%) | catalogued as COSV56595278; called by muse, mutect2
- EPYC | c.899C>A p.P300H | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53798686, COSV53800095; called by muse, mutect2, varscan2
- ERG | c.443A>C p.Q148P | Missense Mutation (SNP) | VAF 8/105 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV55727958; called by muse, mutect2
- ESR2 | c.1501C>T p.R501C | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as rs528840784, COSV50828992; called by muse, mutect2, varscan2
- ETNPPL | c.841G>A p.G281S | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56594815, COSV56595625; called by muse, mutect2, varscan2
- EXT2 | c.1654G>T p.G552C (on ENST00000343631; = p.G585C on NM_000401.3) | Missense Mutation (SNP) | VAF 21/191 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100640528, COSV59146368; called by muse, mutect2, varscan2
- EXT2 | c.1655G>T p.G552V (on ENST00000343631; = p.G585V on NM_000401.3) | Missense Mutation (SNP) | VAF 20/190 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100640529; called by muse, mutect2, varscan2
- F13A1 | c.29G>A p.G10E | Missense Mutation (SNP) | VAF 21/191 reads (11%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.043); catalogued as COSV53554408; called by muse, mutect2, varscan2
- F8 | c.4996C>T p.Q1666* | Nonsense Mutation (SNP) | VAF 7/48 reads (15%) | catalogued as COSV64270193; called by muse, mutect2, varscan2
- FAM171B | c.1189G>T p.V397F | Missense Mutation (SNP) | VAF 46/247 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.767); catalogued as COSV59001183; called by muse, mutect2, varscan2
- FAM47C | c.484G>C p.A162P | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV63724173, COSV63727538; called by muse, mutect2, varscan2
- FAM47C | c.1031C>T p.P344L | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.519); catalogued as rs1251517581, COSV63724190; called by muse, mutect2, varscan2
- FAM53B | c.793C>T p.R265C | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1043962767; called by muse, mutect2, varscan2
- FAM83C | c.603C>A p.Y201* | Nonsense Mutation (SNP) | VAF 27/129 reads (21%) | catalogued as COSV65582262, COSV65584138; called by muse, mutect2, varscan2
- FBN2 | c.4862G>A p.C1621Y | Missense Mutation (SNP) | VAF 37/366 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52496462, COSV52547611; called by muse, mutect2
- FBXO40 | c.1802T>G p.V601G | Missense Mutation (SNP) | VAF 7/136 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0.295); catalogued as COSV57522345; called by muse, mutect2
- FCRL4 | c.917T>A p.L306Q | Missense Mutation (SNP) | VAF 30/135 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54860250; called by muse, mutect2, varscan2
- FER1L6 | c.4814C>A p.T1605N | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV67548408; called by muse, mutect2, varscan2
- FHDC1 | c.1186G>A p.E396K | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.796); catalogued as COSV52598100; called by muse, mutect2, varscan2
- FHL1 | c.32G>T p.R11M | Missense Mutation (SNP) | VAF 45/160 reads (28%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.957); catalogued as COSV61779961; called by muse, mutect2, varscan2
- FHL5 | c.757G>T p.G253W | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.1); catalogued as COSV58735599; called by muse, mutect2, varscan2
- FLG | c.1882C>G p.Q628E | Missense Mutation (SNP) | VAF 102/455 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.124); catalogued as rs779204654, COSV64237807; called by muse, mutect2, varscan2
- FREM1 | c.4389G>T p.Q1463H | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV66518765; called by muse, mutect2, varscan2
- FRMPD2 | c.922-2A>T p.X308_splice | Splice Site (SNP) | VAF 13/75 reads (17%) | catalogued as COSV59715779; called by muse, mutect2, varscan2
- FRY | c.5921A>T p.E1974V | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.074); catalogued as COSV66566181; called by muse, mutect2, varscan2
- FSIP2 | c.18260C>A p.S6087Y | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100554334; called by muse, mutect2, varscan2
- FUT8 | c.611G>C p.C204S (on ENST00000360689 / NM_001371534.1; = p.C41S on NM_004480.4) | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61280796; called by muse, mutect2, varscan2
- FYCO1 | c.259G>T p.G87W | Missense Mutation (SNP) | VAF 33/153 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56114071; called by muse, mutect2, varscan2
- G2E3 | c.1378G>T p.G460C | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52838833; called by mutect2, varscan2
- GALC | c.1757G>T p.G586V | Missense Mutation (SNP) | VAF 28/319 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54323602; called by muse, mutect2
- GANAB | c.1050G>T p.Q350H | Missense Mutation (SNP) | VAF 103/481 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as COSV60462469; called by muse, mutect2, varscan2
- GAS2 | c.191G>T p.G64V | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53404911; called by muse, mutect2, varscan2
- GDNF | c.459G>T p.E153D | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.125); catalogued as COSV58478486; called by muse, mutect2
- GJB1 | c.123G>T p.E41D | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as CM066092, COSV62139558; called by muse, mutect2, varscan2
- GLRX3 | c.276+1G>T p.X92_splice | Splice Site (SNP) | VAF 29/109 reads (27%) | catalogued as COSV58691719; called by muse, mutect2, varscan2
- GNAQ | c.191G>T p.G64V | Missense Mutation (SNP) | VAF 34/188 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54108142; called by muse, mutect2, varscan2
- GPC5 | c.249G>T p.Q83H | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.95); catalogued as COSV65581502, COSV65582941; called by muse, mutect2, varscan2
- GPR139 | c.464C>A p.T155N | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.295); catalogued as COSV58501876; called by muse, mutect2, varscan2
- GPR141 | c.655C>A p.Q219K | Missense Mutation (SNP) | VAF 64/239 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV57731470; called by muse, mutect2, varscan2
- GPR63 | c.700A>C p.T234P | Missense Mutation (SNP) | VAF 27/144 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as rs866908729, COSV57739865; called by muse, mutect2, varscan2
- GPR63 | c.16G>T p.V6L | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated, low confidence (0.95); PolyPhen benign (0); catalogued as rs1168525347, COSV57739874; called by muse, mutect2, varscan2
- GRIA4 | c.2093C>A p.S698* | Nonsense Mutation (SNP) | VAF 6/37 reads (16%) | catalogued as COSV56884676; called by mutect2, varscan2
- GRID1 | c.919G>T p.D307Y | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV60016391, COSV60052524; called by muse, mutect2, varscan2
- GRIN2D | c.2480T>A p.I827N | Missense Mutation (SNP) | VAF 38/220 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53517920; called by muse, mutect2, varscan2
- GRK2 | c.990C>G p.H330Q | Missense Mutation (SNP) | VAF 9/261 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57950625, COSV57951172; called by muse, mutect2
- GRM8 | c.2096C>A p.T699N | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as COSV58807197; called by muse, mutect2, varscan2
- GRM8 | c.1742C>A p.S581Y | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV58807209, COSV58878853; called by muse, mutect2
- GTF3C1 | c.881A>T p.Y294F | Missense Mutation (SNP) | VAF 20/251 reads (8%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.864); catalogued as COSV62239353; called by muse, mutect2
- GTPBP3 | c.115C>G p.L39V | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.951); catalogued as rs746303532, COSV50173654; called by muse, mutect2, varscan2
- HDAC2 | c.1437A>G p.G479= | Splice Region (SNP) | VAF 11/70 reads (16%) | catalogued as COSV100892567; called by muse, mutect2, varscan2
- HDAC2 | c.769G>A p.A257T | Missense Mutation (SNP) | VAF 31/172 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV64037464; called by muse, mutect2, varscan2
- HDAC4 | c.850C>T p.P284S | Missense Mutation (SNP) | VAF 41/126 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as COSV61860646; called by muse, mutect2, varscan2
- HEATR5A | c.4460C>A p.A1487E | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.811); catalogued as rs757014948, COSV66338870; called by muse, mutect2, varscan2
- HECW1 | c.14T>A p.L5Q | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.995); catalogued as COSV67823496; called by muse, mutect2, varscan2
- HEPH | c.1557G>T p.W519C (on ENST00000343002; = p.W252C on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57960018; called by muse, mutect2, varscan2
- HES2 | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.036); catalogued as COSV64732231; called by muse, mutect2, varscan2
- HHATL | c.1011G>T p.T337= | Splice Region (SNP) | VAF 14/37 reads (38%) | catalogued as COSV55133017; called by muse, mutect2, varscan2
- HMCN1 | c.1247A>G p.Q416R | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as COSV54881632; called by muse, mutect2, varscan2
- HNRNPD | c.777del p.K260Rfs*109 (on ENST00000313899 / NM_031370.3; = p.K260Rfs*60 on NM_002138.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 72/379 reads (19%) | catalogued as COSV100002762; called by mutect2, varscan2
- HOXA1 | c.205C>A p.H69N | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.466); catalogued as COSV56065371; called by muse, mutect2, varscan2
- HOXA2 | c.850C>A p.L284M | Missense Mutation (SNP) | VAF 22/200 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.62); catalogued as rs1278253439, COSV56065380; called by muse, mutect2
- HOXA7 | c.136G>C p.A46P | Missense Mutation (SNP) | VAF 40/166 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as COSV54216847, COSV99636727; called by muse, mutect2, varscan2
- HSPH1 | c.2125G>A p.A709T | Missense Mutation (SNP) | VAF 7/120 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0.313); catalogued as COSV60710458; called by muse, mutect2
- IGFBPL1 | c.506G>T p.G169V | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1186519875, COSV66617825; called by muse, mutect2, varscan2
- IGKV3-15 | c.208G>T p.G70C | Missense Mutation (SNP) | VAF 18/166 reads (11%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.656); catalogued as rs553971399; called by muse, mutect2, varscan2
- IGLON5 | c.469G>T p.V157L | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.14); catalogued as rs201159850, COSV54534813; called by muse, mutect2, varscan2
- IGSF10 | c.7490C>A p.T2497K | Missense Mutation (SNP) | VAF 29/158 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV56370576; called by muse, mutect2, varscan2
- IGSF10 | c.3142G>T p.E1048* | Nonsense Mutation (SNP) | VAF 31/109 reads (28%) | catalogued as COSV56782276, COSV56792468; called by muse, mutect2, varscan2
- IGSF5 | c.166G>T p.A56S | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66029450; called by muse, mutect2, varscan2
- ILF3 | c.1645G>C p.G549R | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.969); catalogued as COSV99139430; called by muse, mutect2, varscan2
- INSL5 | c.66C>A p.S22R | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs778970586, COSV58787976; called by muse, mutect2, varscan2
- INTU | c.2455G>T p.E819* | Nonsense Mutation (SNP) | VAF 9/62 reads (15%) | catalogued as COSV58869828; called by muse, mutect2, varscan2
- IPO8 | c.323+1G>T p.X108_splice | Splice Site (SNP) | VAF 39/127 reads (31%) | catalogued as COSV56239957, COSV56244872; called by muse, mutect2, varscan2
- IQGAP2 | c.98G>T p.R33L | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as rs369302838, COSV57168962; called by muse, mutect2, varscan2
- ISLR | c.509C>T p.T170I | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as rs780036106, COSV51433111; called by muse, mutect2, varscan2
- ISOC1 | c.494G>A p.G165E | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1240441068, COSV51491188; called by muse, mutect2, varscan2
- ITGA2B | c.2077G>T p.A693S | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.802); catalogued as COSV52231435; called by muse, mutect2, varscan2
- JMY | c.2528G>T p.R843I | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.26); catalogued as COSV68659603; called by muse, mutect2, varscan2
- JRK | c.1411G>C p.A471P | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.03); catalogued as COSV70629562; called by muse, mutect2
- KAT6B | c.1993+1G>T p.X665_splice | Splice Site (SNP) | VAF 6/59 reads (10%) | catalogued as COSV54743082; called by muse, mutect2
- KATNAL1 | c.1090A>G p.I364V | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV66062713; called by muse, mutect2, varscan2
- KCNA4 | c.1896G>T p.K632N | Missense Mutation (SNP) | VAF 21/164 reads (13%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); catalogued as COSV60250931; called by muse, mutect2, varscan2
- KCNH1 | c.514G>T p.V172L | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as COSV55071630; called by muse, mutect2, varscan2
- KDM3A | c.448A>G p.I150V | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0.021); catalogued as rs895391110, COSV57218783; called by muse, mutect2, varscan2
- KIAA1109 | c.12352G>T p.G4118C | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as COSV52664312; called by muse, mutect2, varscan2
- KIAA1549L | c.1835C>A p.T612N (on ENST00000321505; = p.T909N on NM_012194.3) | Missense Mutation (SNP) | VAF 14/167 reads (8%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.052); catalogued as COSV55770406; called by muse, mutect2
- KLHL20 | c.1293G>T p.E431D | Missense Mutation (SNP) | VAF 30/153 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV52940557; called by muse, mutect2, varscan2
- KLHL6 | c.1661C>G p.A554G | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.46); catalogued as COSV100384738, COSV58064813; called by muse, mutect2, varscan2
- KLK4 | c.285G>T p.Q95H | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV60675824, COSV60677017; called by muse, mutect2, varscan2
- KRT15 | c.687G>C p.Q229H | Missense Mutation (SNP) | VAF 9/137 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.768); catalogued as COSV54182263, COSV99563279; called by muse, mutect2
- KRT6A | c.584G>T p.W195L | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as COSV58104048; called by muse, mutect2, varscan2
- KRTAP10-8 | c.547G>T p.A183S | Missense Mutation (SNP) | VAF 81/435 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.012); catalogued as COSV58166017, COSV58166627; called by muse, mutect2, varscan2
- KRTAP12-2 | c.203T>A p.M68K | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as COSV59963822; called by muse, mutect2
- LAMC1 | c.2042G>T p.G681V | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51133675; called by muse, mutect2, varscan2
- LARP4B | c.1805C>T p.P602L | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.071); catalogued as rs1414430676, COSV60220220; called by muse, mutect2, varscan2
- LBP | c.911C>A p.T304K | Missense Mutation (SNP) | VAF 32/134 reads (24%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.627); catalogued as COSV54138968; called by muse, varscan2
- LCOR | c.3532T>A p.F1178I | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV53714662; called by muse, mutect2
- LELP1 | c.185C>A p.P62H | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64202309; called by muse, mutect2, varscan2
- LETMD1 | c.206G>T p.G69V | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.143); catalogued as COSV50396781; called by muse, mutect2, varscan2
- LGALS9 | c.191C>T p.P64L | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); catalogued as COSV56348141; called by muse, mutect2, varscan2
- LGI3 | c.1519G>T p.E507* | Nonsense Mutation (SNP) | VAF 11/62 reads (18%) | catalogued as COSV60443023; called by mutect2, varscan2
- LHCGR | c.583A>C p.N195H | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54293448; called by muse, mutect2, varscan2
- LILRB1 | c.1631C>A p.S544* (on ENST00000427581; = p.S494* on NM_006669.6) | Nonsense Mutation (SNP) | VAF 32/169 reads (19%) | catalogued as COSV61116402; called by muse, mutect2, varscan2
- LIPK | c.111G>C p.Q37H | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV68200711; called by muse, mutect2
- LONRF3 | c.1948G>T p.D650Y (on ENST00000371628 / NM_001031855.3; = p.D609Y on NM_024778.5) | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100504266, COSV59150402; called by muse, mutect2, varscan2
- LOXL4 | c.1172C>A p.P391H | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV53255527; called by muse, mutect2, varscan2
- LPA | c.4865A>T p.Q1622L | Missense Mutation (SNP) | VAF 31/142 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.053); catalogued as COSV60297972; called by muse, mutect2, varscan2
- LRAT | c.655G>T p.A219S | Missense Mutation (SNP) | VAF 19/217 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.013); catalogued as COSV60476607; called by muse, mutect2
- LRIT2 | c.1241G>T p.G414V | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60565398; called by muse, mutect2, varscan2
- LRIT2 | c.1240G>T p.G414* | Nonsense Mutation (SNP) | VAF 28/109 reads (26%) | catalogued as rs199824710, COSV100258534, COSV60564499; called by muse, mutect2, varscan2
- LRPPRC | c.3015G>C p.Q1005H | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV53234833; called by muse, mutect2, varscan2
- LRRC7 | c.3304A>G p.K1102E (on ENST00000651989 / NM_001370785.2; = p.K1069E on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV50417079; called by muse, mutect2, varscan2
- LTBP1 | c.1102G>T p.G368C (on ENST00000404816 / NM_206943.4; = p.G42C on NM_000627.4) | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63181350, COSV63190597; called by muse, mutect2, varscan2
- LZTR1 | c.1398del p.S467Afs*89 | Frame Shift Del (DEL) | VAF 6/35 reads (17%) | catalogued as CM140928, COSV53145166; called by mutect2, pindel, varscan2
- LZTS2 | c.1031G>T p.R344L | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV64650995; called by muse, mutect2, varscan2
- MAGEC1 | c.2095C>A p.L699I | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.063); catalogued as COSV53569035; called by muse, mutect2, varscan2
- MCPH1 | c.2107C>T p.R703C | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761698331, COSV60910693; called by muse, mutect2, varscan2
- MEF2C | c.373G>T p.D125Y | Missense Mutation (SNP) | VAF 24/209 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100425521, COSV60926486; called by muse, mutect2, varscan2
- MEP1A | c.2179G>T p.A727S | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.334); catalogued as COSV57918341; called by muse, mutect2, varscan2
- MEPE | c.1141G>C p.E381Q | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.644); catalogued as COSV63072020; called by muse, varscan2
- METTL4 | c.268C>T p.P90S | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV55247144; called by muse, mutect2, varscan2
- MGAM | c.3422C>A p.S1141Y | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.393); catalogued as COSV72073861; called by muse, mutect2, varscan2
- MICAL3 | c.3970G>T p.V1324L | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.079); catalogued as COSV71588069; called by muse, mutect2, varscan2
- MMP10 | c.1088G>T p.R363I | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV54245588; called by muse, mutect2, varscan2
- MMP9 | c.62C>T p.P21L | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.997); catalogued as COSV64884321; called by muse, mutect2, varscan2
- MNDA | c.742C>A p.H248N | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.4); catalogued as COSV63740075; called by muse, mutect2, varscan2
- MRGPRX3 | c.548G>A p.W183* | Nonsense Mutation (SNP) | VAF 8/120 reads (7%) | catalogued as COSV66933290; called by muse, mutect2
- MSLN | c.705-2A>T p.X235_splice | Splice Site (SNP) | VAF 4/18 reads (22%) | catalogued as COSV53499669; called by mutect2, varscan2
- MUC16 | c.33710C>A p.S11237* | Nonsense Mutation (SNP) | VAF 7/20 reads (35%) | catalogued as COSV67449711; called by muse, mutect2, varscan2
- MUC2 | c.433C>A p.L145I | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.094); catalogued as rs1488053760; called by muse, mutect2, varscan2
- MUC21 | c.953C>A p.S318Y | Missense Mutation (SNP) | VAF 24/259 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); catalogued as rs748992183, COSV100888839; called by muse, mutect2, varscan2
- MUSK | c.2500C>A p.L834I | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51878545; called by muse, mutect2, varscan2
- MXRA5 | c.2410T>G p.L804V | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54226312; called by muse, mutect2, varscan2
- MYB | c.1828C>A p.P610T | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV57196289; called by muse, mutect2, varscan2
- MYH1 | c.4809C>A p.S1603R | Missense Mutation (SNP) | VAF 34/185 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as COSV56844561; called by muse, varscan2
- MYO1D | c.394G>T p.E132* | Nonsense Mutation (SNP) | VAF 19/91 reads (21%) | catalogued as COSV59008301; called by muse, mutect2, varscan2
- MYO1G | c.628G>C p.G210R | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV51853360; called by muse, mutect2, varscan2
- NBAS | c.4349G>T p.G1450V | Missense Mutation (SNP) | VAF 17/188 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55714234; called by muse, mutect2
- NBEA | c.3233C>A p.P1078Q | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.26); catalogued as COSV59764301; called by muse, mutect2, varscan2
- NCAPH | c.455A>G p.K152R | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53635256; called by muse, mutect2, varscan2
- NDST4 | c.1814C>G p.T605R | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52110805; called by muse, mutect2
- NEDD4 | c.2735A>G p.N912S (on ENST00000508342 / NM_001284338.1; = p.N493S on NM_006154.4) | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV59059163; called by muse, mutect2, varscan2
- NHSL2 | c.1930G>T p.V644L (on ENST00000510661; = p.V1010L on NM_001013627.2) | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.03); catalogued as COSV65452562; called by muse, mutect2, varscan2
- NID1 | c.1379C>A p.S460Y | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51615832; called by muse, mutect2, varscan2
- NID1 | c.1250G>T p.G417V | Missense Mutation (SNP) | VAF 23/138 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV51615849; called by muse, mutect2, varscan2
- NIPAL3 | c.802G>T p.D268Y | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50230305; called by muse, mutect2
- NLRP14 | c.3251A>T p.E1084V | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.22); catalogued as COSV55064700; called by muse, mutect2, varscan2
- NLRP2 | c.2290G>T p.G764C | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54752874; called by muse, mutect2, varscan2
- NLRP3 | c.1051G>T p.V351L | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as CM060243, CM071606, COSV60220950; called by muse, mutect2, varscan2
- NLRP4 | c.617C>A p.S206Y | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100015586, COSV56709094; called by muse, mutect2, varscan2
- NLRP4 | c.1267G>T p.G423W | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56709107, COSV56714256; called by mutect2, varscan2
- NMRK2 | c.376G>T p.E126* | Nonsense Mutation (SNP) | VAF 7/31 reads (23%) | catalogued as COSV51454954, COSV99396383; called by muse, mutect2, varscan2
- NMUR1 | c.629G>A p.R210Q | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.647); catalogued as rs775345754, COSV59403614; called by muse, mutect2, varscan2
- NOS1AP | c.1191G>T p.E397D | Missense Mutation (SNP) | VAF 28/210 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV62632536; called by muse, mutect2, varscan2
- NOTCH4 | c.4183G>T p.D1395Y | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV66679167, COSV66679207; called by muse, mutect2, varscan2
- NPY2R | c.871G>T p.V291F | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.47); catalogued as COSV61527392; called by muse, mutect2, varscan2
- NTAQ1 | c.392G>T p.R131I | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54873826, COSV54876634; called by muse, mutect2
- NUF2 | c.276-1G>T p.X92_splice | Splice Site (SNP) | VAF 11/80 reads (14%) | catalogued as COSV54842363; called by muse, mutect2, varscan2
- NUGGC | c.1886A>G p.K629R | Missense Mutation (SNP) | VAF 19/163 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as COSV58432892; called by muse, mutect2, varscan2
- OBSCN | c.16484C>A p.S5495* | Nonsense Mutation (SNP) | VAF 31/157 reads (20%) | catalogued as COSV52747622; called by muse, mutect2, varscan2
- OGN | c.70C>A p.Q24K | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV99363999; called by muse, mutect2, varscan2
- OR14A16 | c.478G>T p.G160C | Missense Mutation (SNP) | VAF 21/169 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.434); catalogued as COSV62926213; called by muse, mutect2, varscan2
- OR2B11 | c.822G>T p.Q274H | Missense Mutation (SNP) | VAF 40/197 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV59509455; called by muse, mutect2, varscan2
- OR2G2 | c.467T>C p.I156T | Missense Mutation (SNP) | VAF 24/199 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV60739619; called by muse, mutect2, varscan2
- OR2L3 | c.549G>A p.M183I | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.17); catalogued as COSV63454631; called by muse, varscan2
- OR2M7 | c.257T>A p.L86* | Nonsense Mutation (SNP) | VAF 68/408 reads (17%) | catalogued as COSV58738152; called by muse, mutect2, varscan2
- OR2M7 | c.5C>A p.A2E | Missense Mutation (SNP) | VAF 29/231 reads (13%) | SIFT tolerated (0.64); PolyPhen benign (0.013); catalogued as COSV58738159; called by muse, mutect2, varscan2
- OR2T10 | c.122G>C p.W41S | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV100393641, COSV57896246; called by muse, mutect2, varscan2
- OR2T34 | c.614A>T p.Y205F | Missense Mutation (SNP) | VAF 45/301 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.173); catalogued as COSV60899780, COSV60900889; called by muse, mutect2, varscan2
- OR2W3 | c.423C>G p.C141W | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64456220, COSV64456361, COSV64456545; called by muse, mutect2, varscan2
- OR4A15 | c.215C>A p.S72Y | Missense Mutation (SNP) | VAF 38/167 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.172); catalogued as COSV59033850, COSV59034664; called by muse, mutect2, varscan2
- OR4B1 | c.571T>C p.F191L | Missense Mutation (SNP) | VAF 9/138 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.297); catalogued as COSV58882160; called by muse, mutect2
- OR4D5 | c.333G>T p.K111N | Missense Mutation (SNP) | VAF 36/125 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as COSV58305900; called by muse, mutect2, varscan2
- OR4D6 | c.206T>C p.L69P | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); catalogued as COSV55659131; called by mutect2, varscan2
- OR51Q1 | c.885T>A p.S295R | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as COSV56178029; called by muse, mutect2, varscan2
- OR52B4 | c.127G>T p.G43W | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68768633; called by muse, mutect2
- OR52K1 | c.859C>G p.P287A | Missense Mutation (SNP) | VAF 41/180 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.307); catalogued as COSV56903092; called by muse, mutect2, varscan2
- OR5K3 | c.757C>A p.L253I | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.158); catalogued as COSV67349767; called by muse, mutect2, varscan2
- OR6B2 | c.7G>C p.G3R | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV68791328; called by muse, mutect2, varscan2
- OR6C1 | c.127C>A p.L43I | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV101110430, COSV65572776; called by muse, mutect2, varscan2
- OR6K2 | c.190A>T p.S64C | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.043); catalogued as COSV62743167; called by muse, mutect2, varscan2
- OR8J1 | c.550C>A p.L184M | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57316855; called by muse, mutect2, varscan2
- OSBPL6 | c.2605G>T p.A869S | Missense Mutation (SNP) | VAF 33/203 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV51912195; called by muse, mutect2, varscan2
- OTOA | c.2058+1G>T p.X686_splice (on ENST00000286149; = p.X672_splice on NM_144672.4) | Splice Site (SNP) | VAF 18/99 reads (18%) | catalogued as COSV53750157; called by muse, mutect2, varscan2
- OTP | c.725C>A p.A242E | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.29); catalogued as COSV60568561; called by muse, mutect2, varscan2
- OXSM | c.1069G>T p.A357S | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.377); catalogued as COSV55000854, COSV99772001; called by muse, mutect2, varscan2
- PALB2 | c.2956G>T p.D986Y | Missense Mutation (SNP) | VAF 16/201 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV55162891; called by muse, mutect2
- PALD1 | c.871G>T p.E291* | Nonsense Mutation (SNP) | VAF 6/55 reads (11%) | catalogued as COSV54971230; called by muse, mutect2, varscan2
- PAPLN | c.800G>C p.R267P (on ENST00000554301; = p.R240P on NM_173462.4) | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.586); catalogued as COSV53724713, COSV99389246; called by muse, mutect2
- PAPPA2 | c.215C>G p.P72R | Missense Mutation (SNP) | VAF 37/233 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV62774202; called by muse, mutect2, varscan2
- PAQR9 | c.377C>A p.A126E | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as COSV61417691, COSV61418890; called by muse, mutect2, varscan2
- PARP8 | c.1304G>A p.S435N | Missense Mutation (SNP) | VAF 14/133 reads (11%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as COSV55856668; called by muse, mutect2, varscan2
- PCDH10 | c.2843G>T p.G948V | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV52088555; called by muse, mutect2, varscan2
- PCDHB7 | c.1402C>A p.L468M | Missense Mutation (SNP) | VAF 23/178 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.856); catalogued as COSV50755814, COSV50775321; called by muse, mutect2, varscan2
- PCDHGA8 | c.767C>A p.P256H | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs756625630, COSV53908987; called by muse, mutect2, varscan2
- PCDHGA9 | c.2157G>T p.W719C | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.982); catalogued as COSV53909016; called by muse, mutect2, varscan2
- PCYT1B | c.611A>T p.D204V | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV63264203; called by muse, mutect2, varscan2
- PDIA2 | c.187C>A p.L63M | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.892); catalogued as COSV51984142; called by muse, mutect2, varscan2
- PDILT | c.1033G>T p.A345S | Missense Mutation (SNP) | VAF 34/186 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.101); catalogued as rs747898472, COSV56699985, COSV56701372; called by muse, mutect2, varscan2
- PDZD9 | c.395T>G p.V132G (on ENST00000424898 / NM_001363519.1; = p.V72G on NM_173806.4) | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as COSV51671039; called by muse, mutect2, varscan2
- PDZRN3 | c.2867G>T p.G956V | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747778714, COSV55192349, COSV99731424; called by muse, varscan2
- PDZRN3 | c.2777G>C p.R926P | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55192373; called by muse, varscan2
- PECR | c.478C>T p.P160S | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV54733625; called by muse, mutect2, varscan2
- PHACTR3 | c.824C>T p.P275L | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); catalogued as COSV63025612; called by mutect2, varscan2
- PHLDA1 | c.734G>T p.R245L | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.79); catalogued as COSV56996736, COSV56996832; called by muse, varscan2
- PI4KB | c.300G>T p.E100D (on ENST00000368873 / NM_001369623.1; = p.E112D on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT tolerated, low confidence (0.27); PolyPhen possibly damaging (0.584); catalogued as COSV55015593; called by muse, mutect2, varscan2
- PIK3CG | c.2391+1G>T p.X797_splice | Splice Site (SNP) | VAF 8/61 reads (13%) | catalogued as COSV100782643; called by muse, mutect2, varscan2
- PIP5K1A | c.343G>T p.V115L (on ENST00000368888 / NM_001135638.2; = p.V102L on NM_003557.3) | Missense Mutation (SNP) | VAF 28/167 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.303); catalogued as COSV62957543; called by muse, mutect2, varscan2
- PKHD1L1 | c.8535C>A p.H2845Q | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV65738596; called by muse, mutect2, varscan2
- PKNOX2 | c.1076C>A p.A359D | Missense Mutation (SNP) | VAF 24/263 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as COSV53541886; called by muse, mutect2
- PLB1 | c.3454C>A p.L1152I | Missense Mutation (SNP) | VAF 16/208 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV59820313, COSV59835523; called by muse, mutect2
- PLB1 | c.4050C>A p.F1350L | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as COSV59820331; called by muse, varscan2
- PLCB1 | c.3409G>T p.D1137Y | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100569763; called by muse, mutect2, varscan2
- PLCE1 | c.2575C>A p.Q859K | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.155); catalogued as COSV99593866; called by muse, mutect2, varscan2
- PLCE1 | c.2576A>G p.Q859R | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.347); catalogued as COSV99593873; called by muse, mutect2, varscan2
- PLEKHG3 | c.2105A>G p.N702S (on ENST00000394691; = p.N758S on NM_001308147.2) | Missense Mutation (SNP) | VAF 27/192 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs757599300, COSV55978066; called by muse, mutect2, varscan2
- PLPPR4 | c.926A>C p.Y309S | Missense Mutation (SNP) | VAF 8/119 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV64564647; called by muse, mutect2
- PLXND1 | c.4994-1G>C p.X1665_splice | Splice Site (SNP) | VAF 16/90 reads (18%) | catalogued as COSV60709986; called by muse, mutect2, varscan2
- PPM1G | c.1305C>A p.F435L | Missense Mutation (SNP) | VAF 17/226 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV59768608; called by muse, mutect2
- PPP1R12B | c.915G>T p.Q305H | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV61113940; called by muse, mutect2, varscan2
- PPP2R1A | c.1115A>T p.Q372L | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV59042818; called by muse, mutect2, varscan2
- PPP2R2B | c.847T>G p.S283A (on ENST00000394409; = p.S349A on NM_181674.2) | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV60755651; called by muse, mutect2
- PRAMEF19 | c.1141A>G p.T381A | Missense Mutation (SNP) | VAF 41/438 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.869); catalogued as rs763111416; called by muse, mutect2
- PRDM16 | c.1870G>T p.D624Y | Missense Mutation (SNP) | VAF 19/154 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV54580933, COSV54607748, COSV54607942; called by muse, mutect2, varscan2
- PRDM5 | c.1657G>A p.A553T | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.61); catalogued as COSV53356651; called by muse, mutect2, varscan2
- PRELP | c.83C>A p.P28H | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.436); catalogued as COSV58115097, COSV58116639; called by muse, mutect2, varscan2
- PRKCB | c.528C>A p.L176= | Splice Region (SNP) | VAF 8/70 reads (11%) | catalogued as COSV57768867; called by mutect2, varscan2
- PRKD1 | c.536G>T p.G179V | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59560745; called by muse, mutect2, varscan2
- PROC | c.549T>A p.C183* | Nonsense Mutation (SNP) | VAF 17/69 reads (25%) | catalogued as COSV52164948; called by muse, mutect2, varscan2
- PRPF38B | c.559-1G>T p.X187_splice | Splice Site (SNP) | VAF 20/88 reads (23%) | catalogued as COSV64223543; called by muse, mutect2, varscan2
- PRPS1L1 | c.373A>T p.I125F | Missense Mutation (SNP) | VAF 30/173 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV72649831; called by muse, mutect2, varscan2
- PRSS12 | c.1864A>T p.R622* | Nonsense Mutation (SNP) | VAF 11/195 reads (6%) | catalogued as rs1171244856; called by muse, mutect2
- PSD | c.1417G>C p.A473P | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.296); catalogued as COSV50042276, COSV50065773; called by muse, mutect2, varscan2
- PSG7 | c.865C>T p.R289C | Missense Mutation (SNP) | VAF 48/445 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.594); catalogued as rs775658996, COSV68444433; called by muse, mutect2, varscan2
- PTAFR | c.865G>T p.D289Y | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59536158, COSV59536571; called by muse, mutect2, varscan2
- PTCHD4 | c.2074G>C p.V692L | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.84); catalogued as COSV59778280, COSV59779193; called by muse, mutect2, varscan2
- PTGFR | c.722G>C p.R241T | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.047); catalogued as COSV66114511, COSV66116048; called by muse, mutect2, varscan2
- PTGFRN | c.1847T>C p.L616P | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); catalogued as COSV67797915; called by muse, mutect2, varscan2
- PTPRZ1 | c.658C>G p.L220V | Missense Mutation (SNP) | VAF 46/199 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1029352780, COSV66431656; called by muse, mutect2, varscan2
- PUM2 | c.1679G>A p.G560D | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57578403; called by muse, mutect2
- QTRT1 | c.682G>C p.G228R | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748388439, COSV51550332, COSV99139017; called by muse, mutect2, varscan2
- R3HDM1 | c.794A>T p.K265I | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51521501; called by muse, mutect2, varscan2
- RAB3C | c.377C>A p.T126N | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.902); catalogued as COSV51432144; called by muse, mutect2, varscan2
- RAB3GAP2 | c.149del p.G50Efs*41 | Frame Shift Del (DEL) | VAF 12/105 reads (11%) | catalogued as COSV52966745; called by mutect2, pindel, varscan2
- RABGEF1 | c.776G>T p.R259L (on ENST00000439720 / NM_001287061.2; = p.R246L on NM_014504.3 and 29 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV53161033; called by muse, mutect2, varscan2
- RABL3 | c.463A>T p.T155S | Missense Mutation (SNP) | VAF 45/338 reads (13%) | SIFT tolerated (0.79); PolyPhen benign (0.023); catalogued as COSV56335162; called by muse, mutect2, varscan2
- RAG1 | c.2683G>T p.V895L | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV55024101; called by muse, mutect2
- RALGPS2 | c.949G>T p.A317S | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.045); catalogued as COSV100243628; called by muse, mutect2, varscan2
- RANGAP1 | c.534G>T p.K178N | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.266); catalogued as COSV62362614; called by muse, mutect2, varscan2
- RAPGEF2 | c.3487G>T p.V1163L | Missense Mutation (SNP) | VAF 7/107 reads (7%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as COSV52425451; called by muse, mutect2
- RAPGEF3 | c.848G>T p.W283L (on ENST00000389212; = p.W241L on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50198845; called by muse, mutect2, varscan2
- RASGRF2 | c.1996C>A p.L666M | Missense Mutation (SNP) | VAF 62/338 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54124012; called by muse, varscan2
- RASGRF2 | c.2045T>C p.L682P | Missense Mutation (SNP) | VAF 36/144 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54124024; called by muse, varscan2
- RASSF2 | c.581G>T p.R194L | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369276882, COSV65081772; called by muse, mutect2, varscan2
- RBBP6 | c.1632G>C p.R544S | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.987); catalogued as COSV60503656; called by muse, mutect2, varscan2
- RBM47 | c.481A>T p.M161L | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV55930810; called by muse, mutect2, varscan2
- RBM7 | c.436G>T p.V146L | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.236); catalogued as rs1197876807, COSV64955434; called by muse, mutect2, varscan2
- RCC2 | c.7A>T p.R3W | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.035); catalogued as COSV64905359; called by muse, mutect2, varscan2
- REC114 | c.680C>A p.S227Y | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV58521596; called by muse, mutect2, varscan2
- REG3A | c.374G>T p.S125I | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.129); catalogued as COSV59408670; called by muse, varscan2
- REV1 | c.354C>G p.I118M | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51482430; called by muse, mutect2
- RFC3 | c.661A>T p.R221* | Nonsense Mutation (SNP) | VAF 5/77 reads (6%) | catalogued as COSV66296524; called by muse, mutect2
- RGS22 | c.2123A>G p.Y708C | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760394259, COSV62658145; called by muse, mutect2, varscan2
- RICTOR | c.4258G>T p.G1420C | Missense Mutation (SNP) | VAF 16/234 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV57118145, COSV57121123; called by muse, mutect2
- RIMS1 | c.379G>T p.G127W | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53442305, COSV53450164; called by mutect2, varscan2
- RNH1 | c.1202G>C p.R401P | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100339396, COSV57277143; called by muse, mutect2, varscan2
- ROR2 | c.1821del p.S608Afs*15 | Frame Shift Del (DEL) | VAF 8/76 reads (11%) | catalogued as COSV65219314; called by mutect2, pindel, varscan2
- RPS6KL1 | c.845G>T p.R282M | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.19); catalogued as COSV63580733; called by muse, mutect2, varscan2
- RSPO2 | c.199G>T p.G67W | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52639444; called by muse, mutect2, varscan2
- RUVBL1 | c.141G>T p.E47D | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV59475136; called by muse, mutect2, varscan2
- SAMHD1 | c.1090C>T p.H364Y | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.068); catalogued as rs761616206, COSV53428585; called by muse, mutect2, varscan2
- SCAF11 | c.2711G>T p.G904V | Missense Mutation (SNP) | VAF 48/195 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV65475262; called by muse, mutect2, varscan2
- SCG2 | c.739G>T p.G247* | Nonsense Mutation (SNP) | VAF 65/249 reads (26%) | catalogued as COSV100544872, COSV59539229; called by muse, mutect2, varscan2
- SCN1A | c.2509G>T p.G837C (on ENST00000303395 / NM_001202435.3; = p.G826C on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.026); catalogued as COSV57662590; called by muse, mutect2, varscan2
- SCN9A | c.2822A>T p.Q941L (on ENST00000303354; = p.Q930L on NM_002977.3) | Missense Mutation (SNP) | VAF 45/293 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.672); catalogued as COSV57602235; called by muse, mutect2, varscan2
- SCRN1 | c.1066G>A p.A356T | Missense Mutation (SNP) | VAF 37/256 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV54128723; called by muse, mutect2, varscan2
- SCRN1 | c.622G>C p.A208P | Missense Mutation (SNP) | VAF 59/261 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54128739; called by muse, mutect2, varscan2
- SEC13 | c.258G>C p.W86C (on ENST00000350697 / NM_183352.3; = p.W89C on NM_030673.4) | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61601343, COSV61602328; called by muse, mutect2, varscan2
- SEC31A | c.3500C>A p.T1167N (on ENST00000355196 / NM_001318120.1; = p.T1128N on NM_016211.4) | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.072); catalogued as COSV52342095; called by muse, mutect2, varscan2
- SEMA3A | c.926A>G p.Q309R | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.08); catalogued as COSV54863214, COSV54870165; called by muse, mutect2
- SERPINA9 | c.151T>A p.F51I | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54073061; called by muse, varscan2
- SERPINA9 | c.38G>C p.G13A | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.391); catalogued as COSV54073079; called by muse, varscan2
- SERPINB12 | c.504T>A p.G168= | Splice Region (SNP) | VAF 11/145 reads (8%) | catalogued as COSV54032267; called by muse, mutect2
- SERTAD2 | c.307G>T p.A103S | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.054); catalogued as COSV57639728; called by muse, mutect2, varscan2
- SETBP1 | c.3815G>C p.S1272T | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.049); catalogued as COSV56314588; called by muse, mutect2
- SH3GL3 | c.301G>T p.G101W | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs559656402, COSV61053890, COSV61056992; called by muse, varscan2
- SHOC1 | c.89C>A p.T30N | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.018); catalogued as COSV59498205; called by muse, mutect2, varscan2
- SHPRH | c.2378G>C p.R793P | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV51605525; called by muse, mutect2, varscan2
- SHROOM4 | c.3566G>A p.G1189D | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV56785390; called by muse, mutect2
- SIGLEC10 | c.2062C>T p.Q688* | Nonsense Mutation (SNP) | VAF 23/97 reads (24%) | catalogued as COSV59479537; called by muse, mutect2, varscan2
- SIGLEC8 | c.121C>A p.L41M | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV58472444; called by muse, varscan2
- SIGLEC9 | c.794G>T p.G265V | Missense Mutation (SNP) | VAF 21/129 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51582875; called by muse, mutect2, varscan2
- SKAP2 | c.313C>T p.Q105* | Nonsense Mutation (SNP) | VAF 19/57 reads (33%) | catalogued as COSV61721770; called by muse, mutect2, varscan2
- SLC10A2 | c.346G>T p.A116S | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.129); catalogued as COSV55357451; called by muse, mutect2, varscan2
- SLC10A7 | c.335G>T p.G112V | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.186); catalogued as COSV53880821; called by muse, mutect2, varscan2
- SLC12A1 | c.391C>A p.L131M | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57708450; called by muse, mutect2, varscan2
- SLC17A9 | c.368T>C p.F123S | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.014); catalogued as rs1283808937, COSV64846909; called by muse, mutect2
- SLC30A3 | c.371G>A p.W124* | Nonsense Mutation (SNP) | VAF 17/82 reads (21%) | catalogued as COSV51984206; called by muse, mutect2, varscan2
- SLC44A1 | c.1585G>T p.V529L | Missense Mutation (SNP) | VAF 31/168 reads (18%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.997); catalogued as COSV58262544; called by muse, mutect2, varscan2
- SLC45A1 | c.1885G>A p.V629M | Missense Mutation (SNP) | VAF 21/248 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs1368134051, COSV57093922; called by muse, mutect2
- SLC4A3 | c.947G>A p.R316Q | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.707); catalogued as rs766023938, COSV56091989; called by muse, mutect2, varscan2
- SLC5A11 | c.644C>T p.A215V | Missense Mutation (SNP) | VAF 44/220 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV61740384; called by muse, mutect2, varscan2
- SLC5A7 | c.29C>A p.A10D | Missense Mutation (SNP) | VAF 28/163 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV50889271; called by muse, mutect2, varscan2
- SLC6A19 | c.653C>T p.T218I | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58669857; called by muse, mutect2, varscan2
- SLC6A5 | c.712G>T p.A238S | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.593); catalogued as COSV54224033, COSV54224296; called by muse, mutect2, varscan2
- SLC8A1 | c.238G>T p.V80L | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.468); catalogued as COSV99064416; called by muse, mutect2
- SLCO2B1 | c.985C>A p.P329T | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.013); catalogued as COSV56933378; called by muse, mutect2, varscan2
- SLIT1 | c.2080G>A p.G694R | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56581393; called by muse, mutect2, varscan2
- SLITRK6 | c.1355C>A p.P452Q | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); catalogued as COSV68389526; called by muse, mutect2
- SMARCA4 | c.4015G>T p.E1339* | Nonsense Mutation (SNP) | VAF 6/11 reads (55%) | catalogued as COSV60788531, COSV60806990; called by muse, mutect2, varscan2
- SMARCAD1 | c.3020G>T p.G1007V | Missense Mutation (SNP) | VAF 34/211 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.299); catalogued as COSV62773170; called by muse, mutect2, varscan2
- SMC4 | c.349A>T p.S117C | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58445575; called by muse, mutect2, varscan2
- SMOC1 | c.1205G>T p.R402L | Missense Mutation (SNP) | VAF 24/262 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs1455506717, COSV62759766, COSV62760557; called by muse, mutect2
- SNIP1 | c.910G>T p.A304S | Missense Mutation (SNP) | VAF 18/186 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56165765; called by muse, mutect2, varscan2
- SORCS3 | c.982C>G p.R328G | Missense Mutation (SNP) | VAF 45/183 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as COSV100865177, COSV63803722; called by muse, mutect2, varscan2
- SPATA20 | c.885G>C p.Q295H (on ENST00000356488 / NM_001258372.1; = p.Q311H on NM_022827.4) | Missense Mutation (SNP) | VAF 23/358 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.036); catalogued as COSV50065924, COSV50069536; called by muse, mutect2
- SPEF2 | c.1535G>T p.G512V | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV61544933; called by muse, mutect2, varscan2
- SPEG | c.7937G>T p.R2646L | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as rs201143360, COSV56664385, COSV56671387; called by muse, mutect2, varscan2
- SPN | c.99G>T p.L33F | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0.423); catalogued as COSV64070009; called by muse, mutect2
- SPRR1B | c.195C>A p.C65* | Nonsense Mutation (SNP) | VAF 33/212 reads (16%) | catalogued as COSV61067471; called by muse, mutect2, varscan2
- SPTBN1 | c.6790G>T p.V2264L | Missense Mutation (SNP) | VAF 24/272 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.12); catalogued as COSV61686131; called by muse, mutect2
- SQSTM1 | c.329G>T p.R110L | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.122); catalogued as COSV62434318; called by muse, mutect2, varscan2
- SRGAP2 | c.1646C>T p.A549V (on ENST00000624873 / NM_001170637.4; = p.A550V on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as COSV55333992; called by muse, mutect2, varscan2
- SRGAP2 | c.3161G>T p.G1054V (on ENST00000624873 / NM_001170637.4; = p.G1055V on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/200 reads (21%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.101); catalogued as COSV55334005; called by muse, mutect2, varscan2
- STARD7 | c.841G>C p.E281Q | Missense Mutation (SNP) | VAF 29/143 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as COSV61525174; called by muse, mutect2, varscan2
- STEAP4 | c.182G>A p.G61D | Missense Mutation (SNP) | VAF 6/126 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.172); catalogued as COSV57328271; called by muse, mutect2
- STIM1 | c.1183C>T p.H395Y | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV56152127; called by muse, mutect2, varscan2
- STK31 | c.2473C>A p.P825T | Missense Mutation (SNP) | VAF 48/171 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV63454440; called by muse, mutect2, varscan2
- STPG2 | c.1369G>A p.D457N | Missense Mutation (SNP) | VAF 19/146 reads (13%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0); catalogued as COSV54787871; called by muse, mutect2, varscan2
- SULT2A1 | c.716T>A p.V239E | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.457); catalogued as COSV55764269; called by muse, mutect2, varscan2
- SYNPO2 | c.847C>T p.R283W | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs914334727, COSV61107476; called by muse, mutect2, varscan2
- SYT6 | c.1399G>T p.V467L (on ENST00000610222 / NM_001366225.1; = p.V382L on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.096); catalogued as COSV65772698; called by muse, mutect2
- SYTL2 | c.252A>T p.A84= | Splice Region (SNP) | VAF 55/226 reads (24%) | catalogued as COSV60356417; called by muse, mutect2, varscan2
- TAF1L | c.1792G>T p.G598C | Missense Mutation (SNP) | VAF 29/223 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV54259118, COSV99644232; called by muse, mutect2, varscan2
- TAF1L | c.1791G>T p.Q597H | Missense Mutation (SNP) | VAF 29/223 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.18); catalogued as COSV54262769, COSV99644233; called by muse, mutect2, varscan2
- TBX22 | c.79C>A p.P27T | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV64785128; called by muse, mutect2
- TBX3 | c.1069G>T p.A357S (on ENST00000257566 / NM_016569.4; = p.A337S on NM_005996.4) | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.76); PolyPhen benign (0.124); catalogued as COSV57469656; called by muse, mutect2, varscan2
- TCEA2 | c.76G>T p.G26* | Nonsense Mutation (SNP) | VAF 9/155 reads (6%) | catalogued as COSV58657286; called by muse, mutect2
- TCF7L2 | c.1319-2A>T p.X440_splice (on ENST00000355995 / NM_001367943.1; = p.X417_splice on NM_030756.5) | Splice Site (SNP) | VAF 7/80 reads (9%) | catalogued as COSV99525401; called by muse, mutect2
- TENM2 | c.1729C>A p.P577T (on ENST00000518659 / NM_001122679.2; = p.P345T on NM_001080428.3) | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.14); catalogued as COSV69124046; called by muse, mutect2, varscan2
- TENM4 | c.2570G>T p.C857F | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV53612327; called by muse, mutect2, varscan2
- TENT5A | c.1115A>T p.H372L | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV60787411; called by muse, mutect2, varscan2
- TESPA1 | c.889C>T p.R297* (on ENST00000316577 / NM_001098815.3; = p.R159* on NM_014796.2 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 21/70 reads (30%) | catalogued as rs764857918, COSV57257521; called by muse, mutect2, varscan2
- TET1 | c.5352G>T p.K1784N | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs1454252323, COSV65382496; called by muse, mutect2, varscan2
- TEX13B | c.245A>T p.Q82L | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV57202254; called by muse, mutect2, varscan2
- TEX2 | c.1798G>T p.E600* | Nonsense Mutation (SNP) | VAF 24/122 reads (20%) | catalogued as COSV51978037; called by muse, mutect2, varscan2
- TFAP2B | c.212C>A p.P71Q | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.145); catalogued as COSV53825533; called by muse, mutect2, varscan2
- TG | c.7620C>A p.Y2540* | Nonsense Mutation (SNP) | VAF 25/120 reads (21%) | catalogued as COSV55067077; called by muse, mutect2, varscan2
- TGFBR3 | c.2278G>T p.E760* | Nonsense Mutation (SNP) | VAF 23/115 reads (20%) | catalogued as COSV53022438; called by muse, mutect2, varscan2
- TGM4 | c.1597C>A p.Q533K | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.05); catalogued as COSV56092980; called by muse, mutect2, varscan2
- TGM7 | c.46A>T p.S16C | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.923); catalogued as COSV71772602; called by muse, mutect2, varscan2
- THSD7A | c.1596G>T p.Q532H | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.017); catalogued as COSV70261105; called by muse, mutect2, varscan2
- TIGD4 | c.457G>T p.G153C | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.156); catalogued as COSV100427862, COSV58549072; called by muse, mutect2, varscan2
- TIMELESS | c.3454G>T p.E1152* | Nonsense Mutation (SNP) | VAF 58/247 reads (23%) | catalogued as COSV57509473; called by muse, mutect2, varscan2
- TKTL2 | c.989C>A p.A330D | Missense Mutation (SNP) | VAF 28/185 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV54917715, COSV54919539; called by muse, mutect2, varscan2
- TLL1 | c.1963A>T p.R655* | Nonsense Mutation (SNP) | VAF 19/89 reads (21%) | catalogued as COSV50263459, COSV50321640; called by muse, mutect2, varscan2
- TOPORS | c.277G>C p.V93L | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.202); catalogued as COSV62116305; called by muse, mutect2
- TP53 | c.217del p.V73Wfs*50 | Frame Shift Del (DEL) | VAF 34/180 reads (19%) | catalogued as CD109812, COSV53023392, COSV53359933, COSV53361901, COSV53625318, COSV99409681; called by mutect2, varscan2
- TPO | c.2656G>A p.E886K | Missense Mutation (SNP) | VAF 32/135 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.156); catalogued as COSV61096265; called by muse, mutect2, varscan2
- TRAM1 | c.135A>T p.K45N | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.138); catalogued as COSV51596845; called by muse, mutect2, varscan2
- TRAM1L1 | c.442G>T p.D148Y | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.949); catalogued as COSV60291369; called by muse, mutect2, varscan2
- TRANK1 | c.8203G>A p.G2735S | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0); catalogued as rs765419817, COSV57143035, COSV57160597; called by muse, mutect2, varscan2
- TRIB2 | c.1001T>A p.M334K | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated (0.87); PolyPhen benign (0.05); catalogued as COSV99330952; called by muse, mutect2, varscan2
- TRIB2 | c.1002G>T p.M334I | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV50223936, COSV99330959; called by muse, mutect2, varscan2
- TRIM55 | c.1236G>A p.Q412= | Splice Region (SNP) | VAF 6/54 reads (11%) | catalogued as COSV99396586; called by muse, mutect2
- TRIM55 | c.1236+1G>T p.X412_splice | Splice Site (SNP) | VAF 6/56 reads (11%) | catalogued as COSV52545690, COSV99396591; called by muse, mutect2
- TRIM71 | c.2449C>T p.R817W | Missense Mutation (SNP) | VAF 9/168 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67470262; called by muse, mutect2
- TRIM75P | c.1316C>A p.T439N | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.421); catalogued as COSV72295808; called by muse, mutect2, varscan2
- TRIML1 | c.1386C>A p.C462* | Nonsense Mutation (SNP) | VAF 14/95 reads (15%) | catalogued as COSV60193516; called by muse, mutect2, varscan2
- TRMT2B | c.709G>A p.G237R | Missense Mutation (SNP) | VAF 48/125 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.635); catalogued as COSV58618627; called by muse, mutect2, varscan2
- TRPM4 | c.2953G>T p.V985L | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV53259986; called by muse, mutect2, varscan2
- TRPV5 | c.758C>A p.T253N | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.84); catalogued as COSV54683514; called by muse, mutect2, varscan2
- TSPAN33 | c.581C>A p.P194H | Missense Mutation (SNP) | VAF 63/294 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.2); catalogued as COSV56825583; called by muse, mutect2, varscan2
- TXNDC12 | c.463C>T p.Q155* | Nonsense Mutation (SNP) | VAF 7/77 reads (9%) | catalogued as COSV65412962; called by muse, mutect2
- UCMA | c.376G>T p.G126C | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66321313, COSV66321927; called by muse, mutect2, varscan2
- UGDH | c.166G>T p.G56* | Nonsense Mutation (SNP) | VAF 12/81 reads (15%) | catalogued as COSV57096859; called by muse, mutect2, varscan2
- UGT2A1 | c.72G>T p.L24F | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54138765; called by muse, mutect2, varscan2
- UGT2A3 | c.827G>A p.G276E | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV52359053; called by muse, mutect2
- UMOD | c.139G>T p.V47F | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); catalogued as COSV56774007; called by muse, varscan2
- UMODL1 | c.1411G>T p.V471L | Missense Mutation (SNP) | VAF 42/191 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.079); catalogued as rs150059583, COSV61159437; called by muse, mutect2, varscan2
- UNC13C | c.2645T>A p.M882K | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.261); catalogued as COSV52848094; called by muse, mutect2, varscan2
- UNC5B | c.782G>T p.R261L | Missense Mutation (SNP) | VAF 9/124 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.939); catalogued as COSV58974958; called by muse, mutect2
- UPRT | c.823G>T p.G275C | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64920006; called by muse, mutect2, varscan2
- USF3 | c.4761C>A p.N1587K | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.138); catalogued as COSV57070355; called by muse, mutect2, varscan2
- USH2A | c.6949G>T p.G2317C | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56335022; called by muse, mutect2, varscan2
- USH2A | c.1493C>A p.T498N | Missense Mutation (SNP) | VAF 30/185 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.062); catalogued as COSV56335038; called by muse, mutect2, varscan2
- USHBP1 | c.463G>A p.G155R | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.659); catalogued as rs528877755, COSV53102475; called by muse, mutect2, varscan2
- USP6 | c.1735G>A p.G579R | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV51476237; called by muse, mutect2, varscan2
- USP8 | c.272G>T p.G91V | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56162742; called by muse, mutect2, varscan2
- VPS13C | c.2662A>G p.T888A (on ENST00000644861 / NM_020821.3; = p.T845A on NM_017684.5) | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV51126776; called by muse, mutect2, varscan2
- VPS16 | c.217G>T p.G73C | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66792615; called by muse, mutect2, varscan2
- VPS25 | c.445C>G p.L149V | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.554); catalogued as COSV53820087, COSV99519538; called by muse, mutect2
- VPS35 | c.305G>C p.G102A | Missense Mutation (SNP) | VAF 19/154 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); catalogued as COSV54477333; called by muse, mutect2, varscan2
- VSNL1 | c.531C>A p.S177R | Missense Mutation (SNP) | VAF 11/132 reads (8%) | SIFT tolerated (0.48); PolyPhen benign (0.019); catalogued as COSV54597763; called by muse, mutect2
- VSTM2A | c.238G>T p.G80C | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.813); catalogued as COSV56492534; called by muse, mutect2, varscan2
- VSTM2A | c.372A>T p.L124F | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56492547; called by muse, mutect2, varscan2
- VWF | c.2974G>T p.V992L | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54613271; called by muse, mutect2, varscan2
- WARS2 | c.136A>G p.I46V | Missense Mutation (SNP) | VAF 18/256 reads (7%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as COSV52476213; called by muse, mutect2
- WDR27 | c.189G>T p.Q63H | Missense Mutation (SNP) | VAF 29/155 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV61205048; called by muse, mutect2, varscan2
- WDR36 | c.1610-1G>T p.X537_splice | Splice Site (SNP) | VAF 7/33 reads (21%) | catalogued as COSV72605091; called by muse, mutect2, varscan2
- YARS2 | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as COSV61401423; called by muse, mutect2, varscan2
- ZAN | c.2306C>A p.S769Y | Missense Mutation (SNP) | VAF 41/216 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.178); catalogued as COSV61805831; called by muse, mutect2, varscan2
- ZBED4 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV53464082; called by muse, mutect2, varscan2
- ZC3H6 | c.2663C>G p.P888R | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as COSV59666282; called by muse, mutect2, varscan2
- ZEB1 | c.2380C>T p.P794S | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.084); catalogued as rs963030640, COSV100313658, COSV58037936; called by muse, mutect2, varscan2
- ZFHX4 | c.7613T>C p.M2538T | Missense Mutation (SNP) | VAF 27/201 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV50550614; called by muse, mutect2, varscan2
- ZFPM2 | c.2114A>G p.H705R | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65872742; called by muse, mutect2, varscan2
- ZMYND11 | c.1307T>C p.V436A | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.164); catalogued as COSV59076674; called by muse, mutect2, varscan2
- ZNF268 | c.1137G>T p.Q379H | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.735); catalogued as COSV99934759; called by muse, mutect2
- ZNF268 | c.1138A>T p.K380* | Nonsense Mutation (SNP) | VAF 9/30 reads (30%) | catalogued as COSV99934762; called by muse, mutect2
- ZNF285 | c.940A>T p.K314* | Nonsense Mutation (SNP) | VAF 16/142 reads (11%) | catalogued as COSV58408173; called by muse, mutect2, varscan2
- ZNF292 | c.2751G>T p.L917F | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.188); catalogued as COSV60536307; called by muse, mutect2, varscan2
- ZNF560 | c.1009G>T p.V337L | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated (0.72); PolyPhen benign (0.239); catalogued as COSV56866162; called by muse, mutect2, varscan2
- ZNF592 | c.571G>C p.V191L | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.061); catalogued as COSV55435363; called by muse, mutect2, varscan2
- ZNF683 | c.1252C>G p.R418G (on ENST00000403843; = p.R398G on NM_173574.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV62873582, COSV62874562; called by muse, mutect2
- ZNF713 | c.198G>T p.E66D (on ENST00000633730 / NM_001366796.2; = p.E79D on NM_182633.3) | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV68887878; called by muse, mutect2, varscan2
- ZNF804B | c.1635G>T p.W545C | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.818); catalogued as COSV60818633; called by muse, mutect2, varscan2
- ZP1 | c.307G>T p.V103L | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.333); catalogued as COSV53923401, COSV53923449; called by mutect2, varscan2
- ZSCAN18 | c.527G>T p.G176V | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.009); catalogued as COSV53730179; called by muse, mutect2, varscan2
- AHNAK2 | c.16224del p.T5409Lfs*2 | Frame Shift Del (DEL) | VAF 11/55 reads (20%) | called by mutect2, pindel, varscan2
- CSMD1 | c.3259del p.L1087Wfs*49 (on ENST00000520002; = p.L1086Wfs*49 on NM_033225.6) | Frame Shift Del (DEL) | VAF 12/105 reads (11%) | called by mutect2, pindel, varscan2
- CYP26A1 | c.641dup p.E215Rfs*119 | Frame Shift Ins (INS) | VAF 18/95 reads (19%) | called by pindel, varscan2
- FAM122A | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- FCGBP | c.814C>A p.Q272K | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- FNBP4 | c.343del p.D115Tfs*13 | Frame Shift Del (DEL) | VAF 18/105 reads (17%) | called by mutect2, pindel, varscan2
- FRG2C | c.703G>T p.V235F | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.55); called by muse, mutect2, varscan2
- IGHG1 | c.672G>C p.G224= | Splice Region (SNP) | VAF 30/135 reads (22%) | called by muse, mutect2, varscan2
- IGKV1-33 | c.38T>A p.L13Q | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- IGKV2D-24 | c.194C>A p.P65Q | Missense Mutation (SNP) | VAF 28/290 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.825); called by muse, mutect2
- IRX6 | c.246G>T p.Q82H | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KRTAP26-1 | c.379C>A p.P127T | Missense Mutation (SNP) | VAF 17/227 reads (7%) | SIFT tolerated (0.8); PolyPhen benign (0.015); called by muse, mutect2
- LILRA6 | c.640C>G p.L214V | Missense Mutation (SNP) | VAF 13/159 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2
- LSP1 | c.905G>T p.G302V | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.494); called by muse, mutect2, varscan2
- MIXL1 | c.502del p.T168Rfs*4 | Frame Shift Del (DEL) | VAF 19/99 reads (19%) | called by mutect2, pindel, varscan2
- PRH2 | c.362C>A p.P121H | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- RGR | c.371-1G>A p.X124_splice | Splice Site (SNP) | VAF 12/175 reads (7%) | called by muse, mutect2
- RSPH10B | c.184del p.Q62Kfs*17 | Frame Shift Del (DEL) | VAF 34/132 reads (26%) | called by mutect2, varscan2
- RTL4 | c.801_802delinsA p.P268Qfs*60 | Frame Shift Del (DEL) | VAF 29/124 reads (23%) | called by pindel, varscan2*
- SAMD9L | c.465del p.K155Nfs*2 | Frame Shift Del (DEL) | VAF 20/147 reads (14%) | called by mutect2, pindel, varscan2
- SPATA31A3 | c.491A>C p.D164A | Missense Mutation (SNP) | VAF 50/404 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.017); called by muse, mutect2
- STAB2 | c.5294dup p.L1765Ffs*29 | Frame Shift Ins (INS) | VAF 19/119 reads (16%) | called by mutect2, pindel, varscan2
- SUPT20HL2 | c.1044G>T p.W348C | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- TLL2 | c.522dup p.S175Efs*7 | Frame Shift Ins (INS) | VAF 7/45 reads (16%) | called by mutect2, pindel, varscan2
- TRAV12-2 | c.42G>C p.Q14H | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- TRAV13-1 | c.301C>A p.P101T | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- TRAV22 | c.88G>T p.D30Y | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- TRBV4-2 | c.53C>A p.P18H | Missense Mutation (SNP) | VAF 9/207 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- WASHC2C | c.3138G>T p.R1046S (on ENST00000336378; = p.R1025S on NM_015262.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/178 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- WDR35 | c.2616_2617del p.C872* (on ENST00000345530 / NM_001006657.2; = p.C861* on NM_020779.4) | Nonsense Mutation (DEL) | VAF 10/88 reads (11%) | called by pindel, varscan2
- ZNF322 | c.1112C>A p.T371K | Missense Mutation (SNP) | VAF 33/339 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZSCAN5A | c.1109A>T p.K370M | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); called by muse, mutect2
- ADCY8 | c.3126C>A p.A1042= | Silent (SNP) | VAF 12/80 reads (15%) | catalogued as COSV53898358, COSV53911273; called by muse, varscan2
- ADPRHL1 | c.72G>A p.K24= | Silent (SNP) | VAF 11/99 reads (11%) | catalogued as COSV60260782; called by muse, mutect2, varscan2
- AGBL1 | c.2272C>A p.R758= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as COSV66850612, COSV66852202; called by muse, mutect2
- ALDH1L1 | c.744G>C p.T248= | Silent (SNP) | VAF 13/107 reads (12%) | catalogued as COSV56411317, COSV56415451; called by muse, varscan2
- ANO6 | c.2056C>T p.L686= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as COSV57657696; called by muse, mutect2, varscan2
- ARHGAP6 | c.1761C>A p.I587= | Silent (SNP) | VAF 25/58 reads (43%) | catalogued as COSV57292426, COSV57304386; called by muse, mutect2, varscan2
- ARHGEF28 | c.2484A>T p.A828= | Silent (SNP) | VAF 33/149 reads (22%) | catalogued as COSV55248680; called by muse, mutect2, varscan2
- ASB10 | c.672G>T p.R224= (on ENST00000420175 / NM_001142459.2; = p.R209= on NM_080871.4) | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as COSV51994634, COSV51997282; called by muse, mutect2
- ASB15 | c.324C>A p.T108= | Silent (SNP) | VAF 20/150 reads (13%) | catalogued as COSV99306298; called by muse, mutect2, varscan2
- B3GNT7 | c.381G>C p.P127= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as COSV55005970; called by muse, mutect2, varscan2
- BEND2 | c.1188C>A p.G396= | Silent (SNP) | VAF 25/67 reads (37%) | catalogued as COSV66215217, COSV66215543; called by muse, mutect2, varscan2
- BNIP2 | c.765A>T p.T255= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as COSV51105222; called by muse, varscan2
- BRINP3 | c.396G>T p.G132= | Silent (SNP) | VAF 30/142 reads (21%) | catalogued as COSV66515015; called by muse, mutect2, varscan2
- C9orf131 | c.3216C>A p.P1072= | Silent (SNP) | VAF 38/246 reads (15%) | catalogued as COSV56609850; called by muse, mutect2, varscan2
- CALHM2 | c.9C>A p.A3= | Silent (SNP) | VAF 25/126 reads (20%) | catalogued as COSV53294521; called by muse, mutect2, varscan2
- CD109 | c.294A>T p.A98= | Silent (SNP) | VAF 18/104 reads (17%) | catalogued as COSV54646080; called by muse, mutect2, varscan2
- CNTN2 | c.807C>A p.P269= | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as rs926391066, COSV59348457; called by muse, mutect2, varscan2
- CNTN6 | c.1980A>C p.A660= | Silent (SNP) | VAF 16/66 reads (24%) | catalogued as COSV63163799; called by muse, mutect2, varscan2
- COBL | c.1209G>T p.T403= | Silent (SNP) | VAF 22/94 reads (23%) | catalogued as COSV54339823, COSV54353011; called by muse, mutect2, varscan2
- COL22A1 | c.1431C>A p.S477= | Silent (SNP) | VAF 25/99 reads (25%) | catalogued as COSV57326454; called by muse, mutect2, varscan2
- COL3A1 | c.3381G>A p.Q1127= | Silent (SNP) | VAF 11/77 reads (14%) | catalogued as COSV58582992; called by muse, mutect2, varscan2
- CPED1 | c.2838A>T p.L946= | Silent (SNP) | VAF 33/170 reads (19%) | catalogued as rs760984728, COSV100120268; called by muse, mutect2, varscan2
- CSMD3 | c.2877A>T p.S959= (on ENST00000297405 / NM_001363185.1; = p.S855= on NM_052900.3) | Silent (SNP) | VAF 11/112 reads (10%) | catalogued as COSV52116045; called by muse, mutect2
- CYB561A3 | c.222G>C p.G74= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as COSV53651009; called by muse, mutect2, varscan2
- DACH2 | c.390C>A p.I130= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as COSV64163065; called by muse, mutect2, varscan2
- ELOVL3 | c.453A>T p.T151= | Silent (SNP) | VAF 58/201 reads (29%) | catalogued as COSV64174185; called by muse, mutect2, varscan2
- ERN2 | c.1155A>G p.A385= | Silent (SNP) | VAF 16/140 reads (11%) | catalogued as COSV56831909; called by muse, mutect2, varscan2
- ESR1 | c.828C>A p.G276= | Silent (SNP) | VAF 22/132 reads (17%) | catalogued as rs1296595449, COSV52783514; called by muse, mutect2, varscan2
- FAM135B | c.681C>T p.Y227= | Silent (SNP) | VAF 18/144 reads (13%) | catalogued as COSV52709185; called by muse, mutect2, varscan2
- FAM71D | c.1056C>T p.T352= | Silent (SNP) | VAF 9/80 reads (11%) | catalogued as COSV61294783; called by muse, mutect2, varscan2
- FAT3 | c.4860A>T p.L1620= | Silent (SNP) | VAF 67/177 reads (38%) | catalogued as COSV53082578; called by muse, mutect2, varscan2
- FCRLA | c.252G>A p.Q84= (on ENST00000367959; = p.Q61= on NM_032738.4) | Silent (SNP) | VAF 20/94 reads (21%) | catalogued as COSV52684637; called by muse, varscan2
- FOXD4L1 | c.1122A>T p.G374= | Silent (SNP) | VAF 10/134 reads (7%) | catalogued as COSV52073116; called by muse, mutect2
- GABRB1 | c.1266G>T p.G422= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as rs773055387, COSV54972792; called by muse, mutect2, varscan2
- GABRE | c.381C>T p.Y127= | Silent (SNP) | VAF 11/105 reads (10%) | catalogued as rs769124031, COSV64819057; called by muse, mutect2, varscan2
- GABRR1 | c.747C>T p.L249= | Silent (SNP) | VAF 15/131 reads (11%) | catalogued as COSV65618876; called by muse, mutect2, varscan2
- GPR101 | c.1458C>T p.D486= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as rs1381725083, COSV53239464; called by muse, mutect2
- GPR132 | c.81C>A p.G27= | Silent (SNP) | VAF 19/101 reads (19%) | catalogued as COSV61677663; called by muse, mutect2, varscan2
- GRM3 | c.627C>T p.N209= | Silent (SNP) | VAF 12/121 reads (10%) | catalogued as COSV64468098; called by muse, mutect2
- HOXA3 | c.912C>A p.T304= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as COSV57825306; called by muse, mutect2
- IFT80 | c.1521A>T p.T507= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as COSV58445814; called by muse, mutect2, varscan2
- IGKV1-6 | c.96C>A p.S32= | Silent (SNP) | VAF 62/270 reads (23%) | catalogued as rs769768893; called by muse, varscan2
- IGKV5-2 | c.21C>G p.L7= | Silent (SNP) | VAF 5/34 reads (15%) | called by muse, mutect2
- IL27RA | c.564G>T p.L188= | Silent (SNP) | VAF 51/258 reads (20%) | catalogued as COSV54599375; called by muse, mutect2, varscan2
- INSC | c.1023G>T p.R341= | Silent (SNP) | VAF 19/99 reads (19%) | catalogued as COSV65409114; called by muse, mutect2, varscan2
- INTS2 | c.2028C>T p.P676= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV52151340; called by mutect2, varscan2
- ITIH1 | c.1311C>T p.H437= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as COSV56252820; called by muse, mutect2
- KCNK18 | c.315C>T p.S105= | Silent (SNP) | VAF 29/128 reads (23%) | catalogued as COSV57971140; called by muse, mutect2, varscan2
- KCTD3 | c.663G>C p.T221= | Silent (SNP) | VAF 32/214 reads (15%) | catalogued as COSV52064631; called by muse, mutect2, varscan2
- KIRREL3 | c.1401C>T p.R467= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV69383744; called by muse, mutect2, varscan2
- KRT5 | c.1281T>C p.D427= | Silent (SNP) | VAF 24/117 reads (21%) | catalogued as COSV52859265; called by muse, mutect2, varscan2
- LAMA2 | c.1485A>T p.G495= | Silent (SNP) | VAF 22/82 reads (27%) | catalogued as COSV70340333; called by muse, mutect2, varscan2
- LBP | c.864G>T p.T288= | Silent (SNP) | VAF 43/185 reads (23%) | catalogued as COSV54138957, COSV54139604; called by muse, varscan2
- LCE3D | c.6C>A p.S2= | Silent (SNP) | VAF 34/168 reads (20%) | catalogued as COSV64230585; called by muse, varscan2
- LCE4A | c.78C>T p.P26= | Silent (SNP) | VAF 37/239 reads (15%) | catalogued as COSV59266441; called by muse, mutect2, varscan2
- LGI2 | c.759C>T p.N253= | Silent (SNP) | VAF 34/172 reads (20%) | catalogued as COSV66122481, COSV66124315; called by muse, mutect2, varscan2
- LHX9 | c.426C>A p.A142= | Silent (SNP) | VAF 12/93 reads (13%) | catalogued as COSV61327373; called by muse, mutect2, varscan2
- LIG4 | c.2032C>T p.L678= | Silent (SNP) | VAF 10/67 reads (15%) | catalogued as COSV63596538; called by muse, mutect2, varscan2
- LMO4 | c.180C>A p.I60= | Silent (SNP) | VAF 9/82 reads (11%) | catalogued as rs972025244, COSV65170115; called by muse, mutect2
- LRRTM1 | c.825G>T p.V275= | Silent (SNP) | VAF 12/67 reads (18%) | catalogued as COSV54438791; called by muse, mutect2, varscan2
- LRRTM4 | c.1164C>T p.T388= | Silent (SNP) | VAF 6/70 reads (9%) | catalogued as COSV69139170, COSV69141054; called by muse, mutect2
- LSAMP | c.240G>T p.L80= | Silent (SNP) | VAF 18/112 reads (16%) | catalogued as COSV61278341; called by muse, mutect2, varscan2
- MAGEB6B | c.843G>A p.A281= | Silent (SNP) | VAF 22/89 reads (25%) | catalogued as COSV69689749; called by muse, mutect2, varscan2
- MAN2A1 | c.1452G>C p.S484= | Silent (SNP) | VAF 18/65 reads (28%) | catalogued as COSV54846921, COSV54847689; called by muse, mutect2
- MGAM | c.1848G>T p.A616= | Silent (SNP) | VAF 5/57 reads (9%) | catalogued as COSV72073859; called by muse, mutect2
- MGAM | c.4527C>A p.T1509= | Silent (SNP) | VAF 3/17 reads (18%) | catalogued as COSV72073863; called by muse, mutect2
- MID1IP1 | c.96G>A p.V32= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as rs756537342, COSV61230421; called by muse, mutect2, varscan2
- MMEL1 | c.726G>A p.Q242= | Silent (SNP) | VAF 9/87 reads (10%) | catalogued as COSV56519036; called by muse, mutect2, varscan2
- MSC | c.585T>A p.V195= | Silent (SNP) | VAF 139/772 reads (18%) | catalogued as COSV57696210; called by muse, mutect2, varscan2
- MYH2 | c.366C>T p.F122= | Silent (SNP) | VAF 22/103 reads (21%) | catalogued as rs1413745639, COSV55432855, COSV55449267; called by muse, mutect2, varscan2
- MYOM3 | c.3837C>T p.H1279= | Silent (SNP) | VAF 28/282 reads (10%) | catalogued as rs766135314, COSV58390623; called by muse, mutect2
- NACA2 | c.543G>A p.V181= | Silent (SNP) | VAF 15/288 reads (5%) | catalogued as rs878996246, COSV71713093, COSV71713201; called by muse, mutect2
- NDRG2 | c.843C>A p.T281= (on ENST00000298687 / NM_001354570.1; = p.T267= on NM_016250.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as COSV53871883; called by muse, mutect2, varscan2
- NDST3 | c.1977C>A p.V659= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as COSV56613946; called by muse, mutect2, varscan2
- NEB | c.6342C>T p.H2114= | Silent (SNP) | VAF 38/170 reads (22%) | catalogued as COSV50831892; called by muse, mutect2, varscan2
- NEGR1 | c.261G>T p.V87= | Silent (SNP) | VAF 14/126 reads (11%) | catalogued as COSV60832704; called by muse, mutect2, varscan2
- NKIRAS2 | c.549C>T p.N183= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as COSV56917486; called by muse, mutect2, varscan2
- NOBOX | c.859C>T p.L287= | Silent (SNP) | VAF 17/81 reads (21%) | catalogued as COSV56192940; called by muse, mutect2, varscan2
- NPHP3 | c.348G>A p.E116= | Silent (SNP) | VAF 11/79 reads (14%) | catalogued as COSV58128787; called by muse, mutect2, varscan2
- NXF1 | c.576C>T p.N192= | Silent (SNP) | VAF 30/152 reads (20%) | catalogued as COSV53672478; called by muse, mutect2, varscan2
- OCM2 | c.90C>T p.F30= | Silent (SNP) | VAF 20/282 reads (7%) | catalogued as COSV57535180, COSV57535286; called by muse, mutect2
- OGN | c.69C>A p.T23= | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as COSV99364006; called by muse, mutect2, varscan2
- OR2J2 | c.378T>C p.A126= | Silent (SNP) | VAF 41/389 reads (11%) | catalogued as COSV65847772; called by muse, mutect2, varscan2
- OR4L1 | c.222C>T p.S74= | Silent (SNP) | VAF 23/167 reads (14%) | catalogued as COSV59849072; called by muse, mutect2, varscan2
- OR51D1 | c.615C>G p.T205= | Silent (SNP) | VAF 16/115 reads (14%) | catalogued as COSV100712441, COSV62913937; called by muse, mutect2, varscan2
- OR5K1 | c.114C>G p.T38= | Silent (SNP) | VAF 45/288 reads (16%) | catalogued as COSV60303685, COSV60305292; called by muse, mutect2, varscan2
- OR6C6 | c.666C>A p.T222= | Silent (SNP) | VAF 9/86 reads (10%) | called by muse, mutect2, varscan2
- OR6K3 | c.561C>A p.P187= (on ENST00000368146; = p.P171= on NM_001005327.2) | Silent (SNP) | VAF 32/131 reads (24%) | catalogued as COSV63745378; called by muse, mutect2, varscan2
- OR8B12 | c.72C>A p.I24= | Silent (SNP) | VAF 26/127 reads (20%) | catalogued as COSV60911050, COSV60912472; called by muse, mutect2, varscan2
- OR9G4 | c.936A>G p.T312= | Silent (SNP) | VAF 11/120 reads (9%) | catalogued as COSV57247858; called by muse, mutect2
- OTOF | c.3387G>T p.V1129= (on ENST00000272371 / NM_194248.3; = p.V382= on NM_004802.4) | Silent (SNP) | VAF 10/85 reads (12%) | catalogued as COSV55497421; called by muse, mutect2, varscan2
- PCDHA12 | c.135G>T p.V45= | Silent (SNP) | VAF 15/85 reads (18%) | catalogued as COSV56481892; called by muse, mutect2, varscan2
- PCDHA3 | c.1215C>T p.Y405= | Silent (SNP) | VAF 44/238 reads (18%) | catalogued as rs782538317, COSV63539419, COSV63541779; called by muse, mutect2, varscan2
- PCDHB8 | c.1593G>A p.R531= | Silent (SNP) | VAF 27/249 reads (11%) | catalogued as rs782469014, COSV50755816, COSV50774307, COSV50808561; called by muse, mutect2, varscan2
- PCDHGA1 | c.2088G>T p.A696= | Silent (SNP) | VAF 35/192 reads (18%) | catalogued as COSV100965943, COSV65295211; called by muse, mutect2, varscan2
- PCDHGA8 | c.1854G>C p.S618= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as COSV53908996; called by muse, mutect2, varscan2
- PCDHGA9 | c.834A>T p.A278= | Silent (SNP) | VAF 27/122 reads (22%) | catalogued as COSV53909005; called by muse, mutect2, varscan2
- PDE6C | c.2532A>T p.S844= | Silent (SNP) | VAF 14/111 reads (13%) | catalogued as COSV63271120; called by muse, mutect2, varscan2
- PHF14 | c.1437A>T p.S479= | Silent (SNP) | VAF 30/130 reads (23%) | catalogued as COSV68854422; called by muse, mutect2, varscan2
- PHOX2B | c.156G>T p.G52= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as COSV56928671; called by muse, mutect2, varscan2
- PIP4K2B | c.552G>A p.L184= | Silent (SNP) | VAF 9/63 reads (14%) | called by muse, mutect2, varscan2
- PITPNC1 | c.804C>A p.V268= | Silent (SNP) | VAF 8/168 reads (5%) | catalogued as COSV55445922; called by muse, mutect2
- PLB1 | c.4080C>T p.I1360= | Silent (SNP) | VAF 14/90 reads (16%) | catalogued as rs754672534, COSV59820346; called by muse, varscan2
- PLCB1 | c.3408G>T p.L1136= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as COSV100569760; called by muse, mutect2, varscan2
- POLQ | c.2529G>T p.R843= | Silent (SNP) | VAF 24/134 reads (18%) | catalogued as COSV51747107; called by muse, mutect2, varscan2
- PPFIBP1 | c.99T>C p.F33= | Silent (SNP) | VAF 8/150 reads (5%) | catalogued as COSV57288348; called by muse, mutect2
- PPM1E | c.666C>A p.L222= | Silent (SNP) | VAF 18/245 reads (7%) | catalogued as COSV57571507; called by muse, mutect2
- PPP4R4 | c.2262C>T p.P754= | Silent (SNP) | VAF 7/132 reads (5%) | catalogued as rs1253413777, COSV58552601; called by muse, mutect2
- PRR16 | c.669G>T p.R223= (on ENST00000407149 / NM_001300783.2; = p.R200= on NM_016644.2) | Silent (SNP) | VAF 11/70 reads (16%) | catalogued as COSV65395362; called by muse, mutect2, varscan2
- PTPN5 | c.1176G>T p.T392= | Silent (SNP) | VAF 33/153 reads (22%) | catalogued as COSV62125021; called by muse, mutect2, varscan2
- PUDP | c.306G>T p.L102= | Silent (SNP) | VAF 3/21 reads (14%) | catalogued as COSV66903369; called by muse, mutect2
- RAB39B | c.414C>A p.A138= | Silent (SNP) | VAF 27/68 reads (40%) | catalogued as COSV65624385, COSV65624954; called by muse, mutect2, varscan2
- RALGPS2 | c.948G>C p.V316= | Silent (SNP) | VAF 14/69 reads (20%) | catalogued as COSV100243626; called by muse, mutect2, varscan2
- RASSF1 | c.990C>T p.C330= (on ENST00000357043 / NM_170714.2; = p.C326= on NM_007182.5) | Silent (SNP) | VAF 21/137 reads (15%) | catalogued as COSV51700022; called by muse, mutect2, varscan2
- RELCH | c.2928T>A p.T976= | Silent (SNP) | VAF 7/80 reads (9%) | catalogued as COSV56882787; called by muse, mutect2
- RHOBTB2 | c.1692C>T p.T564= | Silent (SNP) | VAF 16/174 reads (9%) | catalogued as COSV52569910; called by muse, mutect2
- RNASE2 | c.324C>A p.I108= | Silent (SNP) | VAF 17/125 reads (14%) | catalogued as COSV100482043, COSV58940896; called by muse, mutect2, varscan2
- RNF17 | c.579G>A p.Q193= | Silent (SNP) | VAF 8/70 reads (11%) | catalogued as COSV55035214; called by muse, mutect2, varscan2
- RP1L1 | c.1722C>A p.P574= | Silent (SNP) | VAF 18/135 reads (13%) | catalogued as COSV66752466; called by muse, mutect2, varscan2
- RTEL1 | c.1161C>T p.A387= | Silent (SNP) | VAF 18/141 reads (13%) | catalogued as rs141241780; called by muse, mutect2, varscan2
- RYR2 | c.3291G>A p.K1097= | Silent (SNP) | VAF 32/167 reads (19%) | catalogued as COSV100768345, COSV63667168; called by muse, mutect2, varscan2
- SCN4A | c.4932G>C p.V1644= | Silent (SNP) | VAF 6/68 reads (9%) | catalogued as COSV71125797; called by muse, mutect2
- SERPINA11 | c.159C>A p.T53= | Silent (SNP) | VAF 60/337 reads (18%) | catalogued as rs770442987, COSV58241288; called by muse, mutect2, varscan2
- SEZ6L | c.2665C>A p.R889= | Silent (SNP) | VAF 27/138 reads (20%) | catalogued as COSV50658802, COSV50679179; called by muse, mutect2, varscan2
- SHANK3 | c.1884G>T p.G628= | Silent (SNP) | VAF 26/138 reads (19%) | catalogued as COSV53184255, COSV99437890; called by muse, mutect2, varscan2
- SLC17A4 | c.123C>A p.L41= | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as COSV64955783; called by muse, mutect2, varscan2
- SLC22A13 | c.708G>T p.G236= | Silent (SNP) | VAF 43/214 reads (20%) | catalogued as COSV61290469; called by muse, mutect2, varscan2
- SLC6A19 | c.678C>A p.T226= | Silent (SNP) | VAF 17/98 reads (17%) | catalogued as COSV58669869; called by muse, varscan2
- SMC1B | c.372A>T p.I124= | Silent (SNP) | VAF 22/113 reads (19%) | catalogued as COSV62528551; called by muse, mutect2, varscan2
- SOX14 | c.232C>A p.R78= | Silent (SNP) | VAF 16/101 reads (16%) | catalogued as COSV60162521; called by muse, mutect2, varscan2
- SPATA31A3 | c.493C>T p.L165= | Silent (SNP) | VAF 48/400 reads (12%) | called by muse, mutect2
- SPEF2 | c.4617G>T p.L1539= | Silent (SNP) | VAF 20/119 reads (17%) | catalogued as COSV57427446; called by muse, mutect2, varscan2
- SRRM2 | c.4299A>G p.R1433= | Silent (SNP) | VAF 13/191 reads (7%) | catalogued as COSV57069263; called by muse, mutect2
- STAP1 | c.159T>A p.T53= | Silent (SNP) | VAF 53/299 reads (18%) | catalogued as rs370473803; called by muse, mutect2, varscan2
- STK32C | c.525C>A p.G175= | Silent (SNP) | VAF 14/68 reads (21%) | catalogued as COSV53838434; called by muse, mutect2, varscan2
- STPG2 | c.982T>C p.L328= | Silent (SNP) | VAF 11/176 reads (6%) | catalogued as COSV54787884; called by muse, mutect2
- SYNE1 | c.3888C>A p.I1296= (on ENST00000367255 / NM_182961.4; = p.I1303= on NM_033071.3) | Silent (SNP) | VAF 24/90 reads (27%) | catalogued as COSV54921622, COSV54956917; called by muse, mutect2, varscan2
- SZT2 | c.8607T>C p.S2869= (on ENST00000634258 / NM_001365999.1; = p.S2812= on NM_015284.4) | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV65167746; called by muse, mutect2, varscan2
- TARS3 | c.2217G>A p.K739= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV60107572; called by muse, mutect2, varscan2
- TDRD6 | c.1734G>T p.V578= | Silent (SNP) | VAF 36/166 reads (22%) | catalogued as COSV60174221; called by muse, mutect2, varscan2
- TH | c.1518G>T p.V506= (on ENST00000381178 / NM_199292.3; = p.V475= on NM_000360.4) | Silent (SNP) | VAF 18/71 reads (25%) | catalogued as COSV51746664; called by muse, mutect2, varscan2
- TMC6 | c.2232G>T p.R744= | Silent (SNP) | VAF 22/150 reads (15%) | catalogued as COSV59808141; called by muse, mutect2, varscan2
- TMEM161B | c.1002G>T p.L334= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as COSV56929593; called by mutect2, varscan2
- TMEM176A | c.459C>T p.I153= | Silent (SNP) | VAF 16/103 reads (16%) | catalogued as COSV50240334; called by muse, mutect2, varscan2
- TNFRSF8 | c.225G>T p.L75= | Silent (SNP) | VAF 14/79 reads (18%) | catalogued as COSV55794877; called by muse, mutect2, varscan2
- TRAV16 | c.271C>T p.L91= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as rs1218550207; called by muse, mutect2, varscan2
- TRAV4 | c.318C>A p.L106= | Silent (SNP) | VAF 12/46 reads (26%) | called by muse, mutect2, varscan2
- TTN | c.18831G>A p.K6277= (on ENST00000591111; = p.K5350= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 28/104 reads (27%) | catalogued as COSV59914907; called by muse, mutect2, varscan2
- USH2A | c.8652G>A p.Q2884= | Silent (SNP) | VAF 58/308 reads (19%) | catalogued as COSV56335008; called by muse, mutect2, varscan2
- USP54 | c.1638G>A p.R546= | Silent (SNP) | VAF 5/60 reads (8%) | catalogued as COSV60440196; called by muse, mutect2
24 further variants in this file (0 protein-altering or splice-affecting, 9 silent, 15 other) are not listed here.
